Somatic mutation profile of tumor specimen TCGA-Z2-A8RT-06A (aliquot TCGA-Z2-A8RT-06A-11D-A372-08) from TCGA case TCGA-Z2-A8RT, project TCGA-SKCM (Skin Cutaneous Melanoma). Sex at birth: female; Vital status: Alive; Primary diagnosis: Malignant melanoma, NOS; Tissue or organ of origin: Skin, NOS; Age at diagnosis: 43.3 years (15,811 days).
Specimen TCGA-Z2-A8RT-06A: Sample type: Metastatic; Tissue type: Tumor; Tumor descriptor: Metastatic; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) fca6b0cb-c82f-47ee-ae92-7666680c66c8.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-Z2-A8RT-10A (Blood Derived Normal), aliquot TCGA-Z2-A8RT-10A-01D-A375-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/082fe333-5914-490c-b411-b9df170d5f09

The open-access MAF lists 3,507 somatic variants for this specimen: 2,286 protein-altering or splice-affecting, 1,124 silent, 97 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 2,106, Silent 1,124, Nonsense Mutation 125, Intron 37, RNA 35, Splice Region 23, Splice Site 17, 5'UTR 8, 3'Flank 7, Translation Start Site 6, 3'UTR 6, Frame Shift Del 6.

Variants (750 of 3,507; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- AR | c.1732G>A p.G578R | Missense Mutation (SNP) | VAF 30/85 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs137852596, CM013691, COSV101017752, COSV65960623; ClinVar: pathogenic; called by muse, mutect2, varscan2
- BRWD3 | c.256G>A p.E86K | Missense Mutation (SNP) | VAF 35/88 reads (40%) | SIFT deleterious (0.02); PolyPhen benign (0.254); catalogued as rs1569290395, COSV100955829; ClinVar: likely pathogenic; called by muse, mutect2, varscan2
- CDKN2A | c.172C>T p.R58* | Nonsense Mutation (SNP) | VAF 8/13 reads (62%) | hotspot (GDC flag); catalogued as rs121913387, CM940227, COSV58682666, COSV58721549, COSV99053472; ClinVar: likely pathogenic / pathogenic; called by muse, mutect2, varscan2
- GATA3 | c.1097G>A p.R366Q | Missense Mutation (SNP) | VAF 16/55 reads (29%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV60519299, COSV60521231; called by muse, mutect2, varscan2
- IREB2 | c.1255C>T p.R419* | Nonsense Mutation (SNP) | VAF 41/112 reads (37%) | catalogued as rs779567692, COSV51921552; ClinVar: likely pathogenic / pathogenic; called by muse, mutect2, varscan2
- SLC4A1 | c.268G>A p.E90K | Missense Mutation (SNP) | VAF 27/74 reads (36%) | SIFT tolerated (0.06); PolyPhen benign (0.029); catalogued as rs28929480, CM011816, COSV52259086; ClinVar: pathogenic; called by muse, mutect2, varscan2
- TNNT2 | c.866G>A p.G289E (on ENST00000236918; = p.G286E on NM_000364.4) | Missense Mutation (SNP) | VAF 8/16 reads (50%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as rs727505233, COSV99372125; ClinVar: likely pathogenic / uncertain significance; called by muse, varscan2
- TP53 | c.645T>G p.S215R | Missense Mutation (SNP) | VAF 20/55 reads (36%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1057520001, CD941799, COSV52752255, COSV52783847, COSV52798196; ClinVar: uncertain significance / likely pathogenic; called by muse, varscan2
- TP53 | c.637C>T p.R213* | Nonsense Mutation (SNP) | VAF 18/58 reads (31%) | hotspot (GDC flag); catalogued as rs397516436, CM951226, COSV52665560, COSV52740638, COSV52746781, COSV52782151; ClinVar: pathogenic; called by muse, varscan2
- A2M | c.1732C>A p.L578I | Missense Mutation (SNP) | VAF 10/35 reads (29%) | SIFT deleterious (0); PolyPhen possibly damaging (0.892); catalogued as COSV100588553; called by muse, mutect2, varscan2
- A2ML1 | c.517G>A p.E173K | Missense Mutation (SNP) | VAF 27/89 reads (30%) | SIFT deleterious (0.01); PolyPhen benign (0.103); catalogued as COSV100228675; called by muse, mutect2, varscan2
- AARS1 | c.556C>T p.P186S | Missense Mutation (SNP) | VAF 91/221 reads (41%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as COSV99933328; called by muse, mutect2, varscan2
- ABCA12 | c.6280G>T p.E2094* (on ENST00000272895 / NM_173076.3; = p.E1776* on NM_015657.3) | Nonsense Mutation (SNP) | VAF 33/88 reads (38%) | catalogued as COSV55970036, COSV99789117; called by muse, mutect2, varscan2
- ABCA12 | c.449C>T p.P150L | Missense Mutation (SNP) | VAF 27/80 reads (34%) | SIFT tolerated (0.86); PolyPhen benign (0); catalogued as COSV99789122; called by muse, mutect2, varscan2
- ABCA13 | c.3233C>T p.S1078F | Missense Mutation (SNP) | VAF 13/34 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.989); catalogued as COSV70029871; called by muse, varscan2
- ABCA13 | c.3269C>T p.S1090L | Missense Mutation (SNP) | VAF 20/55 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV101329976; called by muse, varscan2
- ABCA13 | c.14005C>T p.L4669F | Missense Mutation (SNP) | VAF 16/37 reads (43%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.965); catalogued as rs748573546, COSV101291255, COSV101291306; called by muse, mutect2, varscan2
- ABCA4 | c.1187G>A p.G396E | Missense Mutation (SNP) | VAF 55/136 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as rs866219294, COSV64671282; called by muse, varscan2
- ABCA8 | c.3461G>A p.R1154Q | Missense Mutation (SNP) | VAF 26/63 reads (41%) | SIFT tolerated (0.63); PolyPhen benign (0.001); catalogued as rs550451294, COSV99067430, COSV99285825; called by muse, mutect2, varscan2
- ABCB1 | c.181C>T p.H61Y | Missense Mutation (SNP) | VAF 42/100 reads (42%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1435532727, COSV55961335, COSV99712498; called by muse, mutect2, varscan2
- ABCB11 | c.2552G>A p.R851K | Missense Mutation (SNP) | VAF 78/237 reads (33%) | SIFT tolerated (1); PolyPhen benign (0.007); catalogued as rs1414919070, COSV99791785; called by muse, mutect2, varscan2
- ABCB11 | c.2320T>A p.F774I | Missense Mutation (SNP) | VAF 13/29 reads (45%) | SIFT tolerated (1); PolyPhen benign (0.005); catalogued as rs1245963202, COSV99791788; called by muse, mutect2, varscan2
- ABCB5 | c.1922G>A p.R641K (on ENST00000404938 / NM_001163941.2; = p.R196K on NM_178559.6) | Missense Mutation (SNP) | VAF 29/84 reads (35%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV99327837; called by muse, mutect2, varscan2
- ABCG4 | c.535G>A p.E179K | Missense Mutation (SNP) | VAF 14/20 reads (70%) | SIFT tolerated (0.43); PolyPhen benign (0.031); catalogued as COSV100266631; called by muse, mutect2, varscan2
- ABL1 | c.617C>T p.A206V | Missense Mutation (SNP) | VAF 40/103 reads (39%) | SIFT deleterious (0); PolyPhen benign (0.375); catalogued as COSV59336093; called by muse, mutect2, varscan2
- AC100868.1 | c.1975G>A p.E659K | Missense Mutation (SNP) | VAF 14/24 reads (58%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.267); catalogued as rs183454073; called by muse, mutect2, varscan2
- ACAD11 | c.890G>A p.G297E | Missense Mutation (SNP) | VAF 26/69 reads (38%) | SIFT deleterious (0.04); PolyPhen benign (0.046); catalogued as COSV99391770; called by muse, mutect2, varscan2
- ACAN | c.1276G>A p.A426T | Missense Mutation (SNP) | VAF 15/43 reads (35%) | SIFT tolerated (0.23); PolyPhen benign (0.011); catalogued as COSV100717503; called by muse, mutect2, varscan2
- ACAP1 | c.1505C>T p.S502F | Missense Mutation (SNP) | VAF 10/25 reads (40%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.969); catalogued as COSV99341506; called by muse, mutect2, varscan2
- ACE2 | c.1465G>A p.E489K | Missense Mutation (SNP) | VAF 81/183 reads (44%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.992); catalogued as COSV53024701, COSV99382639; called by muse, mutect2, varscan2
- ACSL4 | c.335G>A p.G112E (on ENST00000340800 / NM_022977.2; = p.G71E on NM_004458.3 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 39/104 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100538390; called by muse, mutect2, varscan2
- ACSM2A | c.1625G>A p.R542K (on ENST00000219054; = p.R463K on NM_001308169.2) | Missense Mutation (SNP) | VAF 67/166 reads (40%) | SIFT deleterious (0.02); PolyPhen probably damaging (1); catalogued as COSV99525054; called by muse, mutect2, varscan2
- ACSM3 | c.835G>A p.G279S | Missense Mutation (SNP) | VAF 58/170 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs749129574, COSV99184228; called by muse, mutect2, varscan2
- ACSS3 | c.1295C>T p.T432I | Missense Mutation (SNP) | VAF 21/70 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV54086947; called by muse, mutect2, varscan2
- ACSS3 | c.1595C>T p.P532L | Missense Mutation (SNP) | VAF 13/40 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.938); catalogued as rs1447376997, COSV99698492; called by muse, mutect2, varscan2
- ACTR3B | c.1235C>T p.P412L | Missense Mutation (SNP) | VAF 55/113 reads (49%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.99); catalogued as COSV99753770, COSV99754117; called by muse, mutect2, varscan2
- ADAM19 | c.334C>T p.H112Y | Missense Mutation (SNP) | VAF 45/132 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (0.948); catalogued as COSV99976600; called by muse, mutect2, varscan2
- ADAM2 | c.1775G>A p.G592E | Missense Mutation (SNP) | VAF 40/113 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV99697030; called by muse, mutect2, varscan2
- ADAM23 | c.2473G>A p.D825N | Missense Mutation (SNP) | VAF 28/59 reads (47%) | SIFT tolerated (0.23); PolyPhen benign (0.348); catalogued as rs924943482, COSV52226816; called by muse, mutect2, varscan2
- ADAM28 | c.1048G>A p.D350N | Missense Mutation (SNP) | VAF 30/112 reads (27%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.999); catalogued as rs777149299, COSV56097980; called by muse, mutect2, varscan2
- ADAM29 | c.1020G>A p.M340I | Missense Mutation (SNP) | VAF 108/161 reads (67%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.863); catalogued as COSV100821942; called by muse, mutect2, varscan2
- ADAM30 | c.1034G>A p.G345E | Missense Mutation (SNP) | VAF 84/225 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV101023796; called by muse, mutect2, varscan2
- ADAM7 | c.674G>A p.R225Q | Missense Mutation (SNP) | VAF 41/92 reads (45%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.933); catalogued as rs1333012683, COSV51535711; called by muse, mutect2, varscan2
- ADAM7 | c.1838G>A p.G613E | Missense Mutation (SNP) | VAF 26/62 reads (42%) | SIFT tolerated (0.23); PolyPhen benign (0.142); catalogued as COSV51542992; called by muse, mutect2, varscan2
- ADAMDEC1 | c.643C>T p.R215W | Missense Mutation (SNP) | VAF 25/79 reads (32%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.586); catalogued as rs541880302, COSV99835925; called by muse, mutect2, varscan2
- ADAMTS10 | c.523G>A p.G175R | Missense Mutation (SNP) | VAF 24/58 reads (41%) | SIFT tolerated (0.31); PolyPhen probably damaging (0.968); catalogued as COSV99546649; called by muse, mutect2, varscan2
- ADAMTS12 | c.1613C>T p.P538L | Missense Mutation (SNP) | VAF 19/54 reads (35%) | SIFT deleterious (0); PolyPhen possibly damaging (0.829); catalogued as COSV100710510; called by muse, mutect2, varscan2
- ADAMTS14 | c.2449G>A p.G817S | Missense Mutation (SNP) | VAF 41/121 reads (34%) | SIFT tolerated (0.24); PolyPhen benign (0.014); catalogued as rs759849405, COSV100941463; called by muse, mutect2, varscan2
- ADAMTS16 | c.2078C>T p.S693F | Missense Mutation (SNP) | VAF 80/176 reads (45%) | SIFT deleterious (0); PolyPhen possibly damaging (0.823); catalogued as COSV99940585; called by muse, mutect2, varscan2
- ADAMTS19 | c.1501G>A p.D501N | Missense Mutation (SNP) | VAF 30/86 reads (35%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as COSV99176809; called by muse, mutect2, varscan2
- ADAMTS20 | c.2936C>T p.S979F | Missense Mutation (SNP) | VAF 37/88 reads (42%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV101166134; called by muse, mutect2, varscan2
- ADAMTS9 | c.2104C>T p.R702* | Nonsense Mutation (SNP) | VAF 56/143 reads (39%) | catalogued as COSV55781008; called by muse, mutect2, varscan2
- ADCY2 | c.395C>T p.S132F | Missense Mutation (SNP) | VAF 34/71 reads (48%) | SIFT tolerated (0.7); PolyPhen benign (0.003); catalogued as COSV100602248; called by muse, mutect2, varscan2
- ADCY7 | c.1406G>A p.R469K | Missense Mutation (SNP) | VAF 23/44 reads (52%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV99575799; called by muse, mutect2, varscan2
- ADGRA1 | c.907G>A p.E303K | Missense Mutation (SNP) | VAF 6/11 reads (55%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0); catalogued as rs1326416706, COSV100811009; called by muse, mutect2
- ADGRB1 | c.2443G>A p.G815R | Missense Mutation (SNP) | VAF 23/34 reads (68%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.812); catalogued as COSV100029411; called by muse, mutect2, varscan2
- ADGRF1 | c.1330G>A p.G444S | Missense Mutation (SNP) | VAF 49/141 reads (35%) | SIFT tolerated (0.16); PolyPhen benign (0.014); catalogued as COSV99347105; called by muse, mutect2, varscan2
- ADGRF4 | c.3G>A p.M1? | Translation Start Site (SNP) | VAF 39/107 reads (36%) | SIFT tolerated, low confidence (0.2); PolyPhen benign (0); catalogued as rs377029853; called by muse, mutect2, varscan2
- ADGRF4 | c.1117G>A p.E373K | Missense Mutation (SNP) | VAF 30/64 reads (47%) | SIFT tolerated (0.85); PolyPhen benign (0.001); catalogued as rs771530266, COSV51951749, COSV51955542; called by muse, mutect2, varscan2
- ADGRG4 | c.62T>A p.F21Y | Missense Mutation (SNP) | VAF 93/241 reads (39%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.96); catalogued as COSV99794914; called by muse, mutect2, varscan2
- ADGRG4 | c.2843G>A p.G948E | Missense Mutation (SNP) | VAF 122/306 reads (40%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.998); catalogued as COSV54955217; called by muse, mutect2, varscan2
- ADGRG4 | c.4940C>T p.S1647F | Missense Mutation (SNP) | VAF 134/321 reads (42%) | SIFT tolerated (0.12); PolyPhen benign (0.024); catalogued as rs928583232, COSV99794918; called by muse, mutect2, varscan2
- ADGRG4 | c.8870T>C p.F2957S | Missense Mutation (SNP) | VAF 140/361 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV99794920; called by muse, mutect2, varscan2
- ADGRL3 | c.1039G>A p.E347K (on ENST00000506720 / NM_001322402.2; = p.E279K on NM_015236.6) | Missense Mutation (SNP) | VAF 13/20 reads (65%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.999); catalogued as COSV101546943; called by muse, mutect2, varscan2
- ADGRL4 | c.630G>A p.W210* | Nonsense Mutation (SNP) | VAF 54/78 reads (69%) | catalogued as rs1395027498, COSV100875755; called by muse, mutect2, varscan2
- AFDN | c.5296G>A p.D1766N (on ENST00000447894 / NM_001366320.1; = p.D1685N on NM_001207008.1) | Missense Mutation (SNP) | VAF 30/65 reads (46%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.151); catalogued as COSV100652720; called by muse, mutect2, varscan2
- AFM | c.844-1G>A p.X282_splice | Splice Site (SNP) | VAF 38/57 reads (67%) | catalogued as COSV99888643; called by muse, mutect2, varscan2
- AGAP6 | c.1633C>T p.R545C (on ENST00000374056 / NM_001365867.1; = p.R568C on NM_001077665.2) | Missense Mutation (SNP) | VAF 73/288 reads (25%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.893); catalogued as rs782697526, COSV65017635; called by muse, mutect2
- AGFG2 | c.641C>T p.P214L | Missense Mutation (SNP) | VAF 61/97 reads (63%) | SIFT tolerated (0.17); PolyPhen benign (0.001); catalogued as COSV99499230; called by muse, mutect2, varscan2
- AGGF1 | c.1870C>T p.R624W | Missense Mutation (SNP) | VAF 56/187 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.938); catalogued as rs148706003; called by muse, mutect2, varscan2
- AGMAT | c.569C>T p.T190M | Missense Mutation (SNP) | VAF 26/79 reads (33%) | SIFT tolerated (0.06); PolyPhen benign (0.223); catalogued as rs200804155; called by muse, mutect2, varscan2
- AGO2 | c.614C>T p.S205F | Missense Mutation (SNP) | VAF 43/72 reads (60%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV55046503; called by muse, mutect2, varscan2
- AK4 | c.424C>T p.P142S | Missense Mutation (SNP) | VAF 22/36 reads (61%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.682); catalogued as COSV100519818; called by muse, mutect2, varscan2
- AKAP3 | c.2128T>G p.F710V | Missense Mutation (SNP) | VAF 22/48 reads (46%) | SIFT tolerated (0.24); PolyPhen benign (0.197); catalogued as COSV99961926; called by muse, mutect2, varscan2
- AKR1C4 | c.450C>T p.V150= | Splice Region (SNP) | VAF 38/93 reads (41%) | catalogued as rs782243403, COSV99578577; called by muse, mutect2, varscan2
- AKR1C4 | c.721C>T p.L241F | Missense Mutation (SNP) | VAF 24/54 reads (44%) | SIFT deleterious (0); PolyPhen probably damaging (0.982); catalogued as COSV54122982, COSV99578579; called by muse, mutect2, varscan2
- AKR1D1 | c.962C>T p.P321L | Missense Mutation (SNP) | VAF 38/206 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99652919; called by muse, mutect2
- AL592490.1 | c.1748C>T p.S583F | Missense Mutation (SNP) | VAF 69/101 reads (68%) | SIFT tolerated (0.14); PolyPhen benign (0.015); catalogued as rs780270613, COSV69424515; called by muse, mutect2, varscan2
- ALDH1A2 | c.424G>A p.G142S | Missense Mutation (SNP) | VAF 52/135 reads (39%) | SIFT tolerated (0.41); PolyPhen benign (0.046); catalogued as COSV99990247; called by muse, mutect2, varscan2
- ALDH1B1 | c.272C>T p.S91F | Missense Mutation (SNP) | VAF 50/76 reads (66%) | SIFT deleterious (0); PolyPhen possibly damaging (0.816); catalogued as COSV66619298; called by muse, mutect2, varscan2
- ALDH8A1 | c.68C>T p.S23L | Missense Mutation (SNP) | VAF 61/154 reads (40%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.589); catalogued as COSV99664556, COSV99664684; called by muse, mutect2, varscan2
- ALG13 | c.2827C>T p.P943S | Missense Mutation (SNP) | VAF 9/15 reads (60%) | SIFT tolerated (0.35); PolyPhen benign (0.01); catalogued as COSV52643880; called by muse, mutect2, varscan2
- ALG6 | c.80C>T p.S27L | Missense Mutation (SNP) | VAF 13/32 reads (41%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.527); catalogued as COSV99673077; called by muse, mutect2, varscan2
- ALK | c.4630A>G p.N1544D | Missense Mutation (SNP) | VAF 136/389 reads (35%) | SIFT tolerated (0.2); PolyPhen benign (0.01); catalogued as COSV101201663; called by muse, mutect2, varscan2
- ALK | c.1231A>C p.N411H | Missense Mutation (SNP) | VAF 31/79 reads (39%) | SIFT tolerated (0.12); PolyPhen possibly damaging (0.869); catalogued as COSV101201666; called by muse, mutect2, varscan2
- ALOX15 | c.216G>T p.K72N | Missense Mutation (SNP) | VAF 27/66 reads (41%) | SIFT tolerated (0.07); PolyPhen benign (0.093); catalogued as rs1170527133, COSV99541263; called by muse, mutect2, varscan2
- ALOX5 | c.523G>A p.G175R | Missense Mutation (SNP) | VAF 27/79 reads (34%) | SIFT tolerated (0.3); PolyPhen possibly damaging (0.793); catalogued as COSV65551723; called by muse, mutect2, varscan2
- ALOX5 | c.524G>A p.G175E | Missense Mutation (SNP) | VAF 29/81 reads (36%) | SIFT tolerated (0.3); PolyPhen benign (0.11); catalogued as COSV100980012; called by muse, mutect2, varscan2
- ALOX5AP | c.481C>T p.P161S | Missense Mutation (SNP) | VAF 21/126 reads (17%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.994); catalogued as rs774719216, COSV100996272; called by muse, mutect2, varscan2
- AMBRA1 | c.1289C>A p.S430Y (on ENST00000458649 / NM_001367468.1; = p.S340Y on NM_017749.3 and 3 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 45/61 reads (74%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.687); catalogued as COSV100093219; called by muse, mutect2, varscan2
- AMER1 | c.787G>A p.E263K | Missense Mutation (SNP) | VAF 85/234 reads (36%) | SIFT tolerated (0.24); PolyPhen benign (0.037); catalogued as COSV100365662, COSV57662113; called by muse, mutect2, varscan2
- AMER3 | c.379A>T p.I127F | Missense Mutation (SNP) | VAF 24/56 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV100366225; called by muse, mutect2, varscan2
- AMPD1 | c.358C>T p.P120S | Missense Mutation (SNP) | VAF 58/163 reads (36%) | SIFT tolerated (0.07); PolyPhen benign (0.14); catalogued as COSV100814955; called by muse, mutect2, varscan2
- AMPD3 | c.208G>A p.E70K (on ENST00000396553 / NM_001025389.2; = p.E79K on NM_000480.3) | Missense Mutation (SNP) | VAF 13/21 reads (62%) | SIFT deleterious (0.04); PolyPhen benign (0.003); catalogued as rs1472302387, COSV101158120; called by muse, mutect2
- AMY1C | c.1022G>A p.G341E | Missense Mutation (SNP) | VAF 62/597 reads (10%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.657); catalogued as COSV100915196; called by muse, mutect2
- ANGPT4 | c.1428G>A p.M476I | Missense Mutation (SNP) | VAF 31/78 reads (40%) | SIFT tolerated (0.11); PolyPhen benign (0.001); catalogued as rs1474770356, COSV101124676; called by muse, mutect2, varscan2
- ANGPTL4 | c.1040-1G>A p.X347_splice | Splice Site (SNP) | VAF 91/272 reads (33%) | catalogued as COSV100035049; called by muse, mutect2, varscan2
- ANGPTL4 | c.1040G>A p.G347E | Missense Mutation (SNP) | VAF 93/272 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100035052; called by muse, mutect2, varscan2
- ANK3 | c.9250G>A p.E3084K | Missense Mutation (SNP) | VAF 61/157 reads (39%) | SIFT deleterious, low confidence (0.03); PolyPhen possibly damaging (0.681); catalogued as COSV99779030; called by muse, mutect2, varscan2
- ANK3 | c.3980C>T p.S1327F (on ENST00000280772 / NM_001320874.2; = p.S461F on NM_001149.3) | Missense Mutation (SNP) | VAF 85/221 reads (38%) | SIFT deleterious (0); PolyPhen possibly damaging (0.459); catalogued as COSV55063627, COSV99779039; called by muse, mutect2, varscan2
- ANK3 | c.3668C>T p.P1223L (on ENST00000280772 / NM_001320874.2; = p.P357L on NM_001149.3) | Missense Mutation (SNP) | VAF 54/111 reads (49%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.997); catalogued as rs749846661, COSV55050194; called by muse, varscan2
- ANK3 | c.1517C>T p.S506L | Missense Mutation (SNP) | VAF 48/146 reads (33%) | SIFT deleterious (0); PolyPhen possibly damaging (0.832); catalogued as COSV99779055; called by muse, mutect2, varscan2
- ANK3 | c.1397G>A p.G466E | Missense Mutation (SNP) | VAF 21/56 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1188174192, COSV99779059; called by muse, mutect2, varscan2
- ANK3 | c.898G>A p.D300N | Missense Mutation (SNP) | VAF 12/48 reads (25%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.999); catalogued as COSV99779061; called by muse, mutect2
- ANKDD1A | c.40C>T p.P14S | Missense Mutation (SNP) | VAF 30/75 reads (40%) | SIFT tolerated (0.08); PolyPhen benign (0.209); catalogued as rs760922307, COSV60354125; called by muse, mutect2, varscan2
- ANKDD1A | c.41C>T p.P14L | Missense Mutation (SNP) | VAF 30/76 reads (39%) | SIFT tolerated (0.14); PolyPhen benign (0.007); catalogued as COSV100132631, COSV60353123; called by muse, mutect2, varscan2
- ANKFN1 | c.198G>A p.W66* | Nonsense Mutation (SNP) | VAF 35/99 reads (35%) | catalogued as COSV59446429; called by muse, mutect2, varscan2
- ANKFN1 | c.1508C>T p.S503F | Missense Mutation (SNP) | VAF 54/102 reads (53%) | SIFT deleterious (0); PolyPhen probably damaging (0.972); catalogued as COSV100593286; called by muse, mutect2, varscan2
- ANKLE1 | c.1948C>T p.L650F (on ENST00000394458; = p.L596F on NM_152363.6) | Missense Mutation (SNP) | VAF 14/36 reads (39%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.926); catalogued as rs779030725, COSV101082168; called by muse, mutect2, varscan2
- ANKMY1 | c.1928C>T p.P643L | Missense Mutation (SNP) | VAF 20/68 reads (29%) | SIFT deleterious (0); PolyPhen possibly damaging (0.842); catalogued as rs1224560035, COSV99801667; called by muse, mutect2, varscan2
- ANKRD12 | c.4851T>G p.H1617Q | Missense Mutation (SNP) | VAF 30/53 reads (57%) | SIFT tolerated, low confidence (0.21); PolyPhen benign (0); catalogued as COSV100040989; called by muse, mutect2, varscan2
- ANKRD26 | c.1826C>T p.A609V | Missense Mutation (SNP) | VAF 25/63 reads (40%) | SIFT tolerated (0.05); PolyPhen benign (0.025); catalogued as COSV101063044; called by muse, mutect2, varscan2
- ANKRD30A | c.774G>A p.M258I (on ENST00000611781; = p.M202I on NM_052997.2) | Missense Mutation (SNP) | VAF 17/41 reads (41%) | SIFT tolerated (0.21); PolyPhen benign (0.005); catalogued as rs761284654, COSV100653155; called by muse, mutect2, varscan2
- ANKRD30A | c.1426G>A p.E476K (on ENST00000611781; = p.E420K on NM_052997.2) | Missense Mutation (SNP) | VAF 42/116 reads (36%) | SIFT tolerated (0.1); PolyPhen possibly damaging (0.899); catalogued as rs867286949, COSV64607688; called by muse, varscan2
- ANKRD30A | c.3382A>C p.K1128Q (on ENST00000611781; = p.K1072Q on NM_052997.2) | Missense Mutation (SNP) | VAF 54/144 reads (38%) | SIFT deleterious (0); PolyPhen benign (0.102); catalogued as COSV100653158, COSV64622358; called by muse, mutect2, varscan2
- ANO2 | c.2704C>T p.R902C (on ENST00000356134 / NM_001278597.3; = p.R906C on NM_001278596.3) | Missense Mutation (SNP) | VAF 6/24 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs545044632, COSV100500214; called by muse, varscan2
- ANO2 | c.1322C>T p.S441F (on ENST00000356134 / NM_001278597.3; = p.S445F on NM_001278596.3) | Missense Mutation (SNP) | VAF 31/89 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as COSV100500221; called by muse, mutect2, varscan2
- ANO4 | c.2548G>A p.G850R (on ENST00000392977 / NM_001286615.2; = p.G815R on NM_178826.4) | Missense Mutation (SNP) | VAF 33/106 reads (31%) | SIFT tolerated (0.14); PolyPhen possibly damaging (0.709); catalogued as COSV100152420; called by muse, mutect2, varscan2
- ANOS1 | c.316G>A p.E106K | Missense Mutation (SNP) | VAF 11/30 reads (37%) | SIFT deleterious (0.02); PolyPhen benign (0.355); catalogued as COSV99390646; called by muse, mutect2, varscan2
- ANXA13 | c.808C>T p.R270C | Missense Mutation (SNP) | VAF 46/72 reads (64%) | SIFT deleterious (0); PolyPhen possibly damaging (0.802); catalogued as rs992360945, COSV51623321; called by muse, mutect2
- AOX1 | c.2497C>T p.R833C | Missense Mutation (SNP) | VAF 30/81 reads (37%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.998); catalogued as rs749776412, COSV65981358; called by muse, mutect2, varscan2
- AP3D1 | c.2504C>T p.P835L | Missense Mutation (SNP) | VAF 10/38 reads (26%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.479); catalogued as COSV61429645; called by muse, mutect2
- AP5Z1 | c.493C>T p.P165S | Missense Mutation (SNP) | VAF 29/82 reads (35%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.693); catalogued as COSV100804046; called by muse, mutect2, varscan2
- APBB1 | c.949T>A p.W317R | Missense Mutation (SNP) | VAF 41/60 reads (68%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.737); catalogued as COSV100193767; called by muse, mutect2, varscan2
- APBB1IP | c.502G>A p.E168K | Missense Mutation (SNP) | VAF 31/73 reads (42%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.876); catalogued as COSV63301661; called by muse, mutect2, varscan2
- APLNR | c.7G>A p.E3K | Missense Mutation (SNP) | VAF 40/62 reads (65%) | SIFT tolerated, low confidence (0.23); PolyPhen benign (0.015); catalogued as COSV57242753; called by muse, mutect2, varscan2
- APMAP | c.410C>T p.S137L | Missense Mutation (SNP) | VAF 34/93 reads (37%) | SIFT tolerated (0.19); PolyPhen benign (0.023); catalogued as rs371061783; called by muse, mutect2, varscan2
- APOA1 | c.188G>A p.G63E | Missense Mutation (SNP) | VAF 33/50 reads (66%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV99369179; called by muse, mutect2, varscan2
- APOB | c.8389G>A p.G2797R | Missense Mutation (SNP) | VAF 60/183 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV51929999; called by muse, mutect2, varscan2
- APOBEC1 | c.604C>T p.H202Y | Missense Mutation (SNP) | VAF 23/72 reads (32%) | SIFT tolerated (0.1); PolyPhen benign (0); catalogued as COSV99981037; called by muse, mutect2, varscan2
- APOBEC3F | c.1093G>A p.D365N | Missense Mutation (SNP) | VAF 141/328 reads (43%) | SIFT tolerated (0.11); PolyPhen benign (0.173); catalogued as COSV100415140; called by muse, mutect2, varscan2
- APOL1 | c.724G>A p.D242N | Missense Mutation (SNP) | VAF 46/96 reads (48%) | SIFT tolerated (0.59); PolyPhen benign (0.001); catalogued as rs752305718, COSV100045985; called by muse, mutect2, varscan2
- APP | c.1595C>T p.T532I | Missense Mutation (SNP) | VAF 16/34 reads (47%) | SIFT deleterious (0); PolyPhen possibly damaging (0.88); catalogued as COSV100695481; called by muse, mutect2, varscan2
- APP | c.1171T>G p.F391V | Missense Mutation (SNP) | VAF 29/111 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV100695482; called by muse, mutect2, varscan2
- AQP10 | c.871C>T p.P291S | Missense Mutation (SNP) | VAF 71/195 reads (36%) | SIFT tolerated (0.21); PolyPhen benign (0.037); catalogued as COSV100270045; called by muse, mutect2, varscan2
- AR | c.1142C>T p.P381L | Missense Mutation (SNP) | VAF 9/28 reads (32%) | SIFT deleterious, low confidence (0.03); PolyPhen benign (0.258); catalogued as rs759045198, COSV65964144; called by muse, mutect2, varscan2
- ARAP3 | c.3605C>T p.S1202F | Missense Mutation (SNP) | VAF 13/36 reads (36%) | SIFT tolerated (0.13); PolyPhen benign (0.007); catalogued as rs772268522, COSV99499480; called by muse, mutect2, varscan2
- ARAP3 | c.1958C>T p.P653L | Missense Mutation (SNP) | VAF 23/66 reads (35%) | SIFT tolerated (0.36); PolyPhen benign (0); catalogued as COSV99499481; called by muse, mutect2, varscan2
- AREG | c.268G>A p.E90K | Missense Mutation (SNP) | VAF 87/140 reads (62%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.921); catalogued as rs765591544, COSV52644609; called by muse, mutect2, varscan2
- ARF3 | c.260G>A p.G87E | Missense Mutation (SNP) | VAF 43/112 reads (38%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.974); catalogued as rs777056448, COSV99873041; called by muse, mutect2, varscan2
- ARFGEF3 | c.5803G>A p.D1935N | Missense Mutation (SNP) | VAF 23/64 reads (36%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.92); catalogued as rs771537463, COSV52475520; called by muse, varscan2
- ARFGEF3 | c.5857G>A p.G1953R | Missense Mutation (SNP) | VAF 12/34 reads (35%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.851); catalogued as rs749072879, COSV99292822; called by muse, varscan2
- ARFGEF3 | c.5858G>A p.G1953E | Missense Mutation (SNP) | VAF 12/34 reads (35%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.797); catalogued as rs1017049413, COSV99292824; called by muse, varscan2
- ARHGAP15 | c.749G>A p.R250Q | Missense Mutation (SNP) | VAF 61/147 reads (41%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.749); catalogued as rs751971221, COSV54488577, COSV54530458; called by muse, mutect2, varscan2
- ARHGAP21 | c.131C>T p.S44F | Missense Mutation (SNP) | VAF 37/95 reads (39%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.828); catalogued as rs770467400, COSV100903547; called by muse, mutect2, varscan2
- ARHGAP22 | c.1993G>A p.D665N | Missense Mutation (SNP) | VAF 42/109 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as rs369571815; called by muse, mutect2, varscan2
- ARHGAP22 | c.153G>A p.M51I | Missense Mutation (SNP) | VAF 82/231 reads (35%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.718); catalogued as COSV99984803; called by muse, mutect2, varscan2
- ARHGAP26 | c.2093C>T p.P698L | Missense Mutation (SNP) | VAF 63/150 reads (42%) | SIFT tolerated (0.2); PolyPhen probably damaging (0.996); catalogued as COSV99189883; called by muse, mutect2, varscan2
- ARHGAP28 | c.695G>A p.G232E (on ENST00000383472 / NM_001366230.1; = p.G73E on NM_001010000.3) | Missense Mutation (SNP) | VAF 80/120 reads (67%) | SIFT tolerated (0.35); PolyPhen benign (0.082); catalogued as rs867071340, COSV99149124; called by muse, mutect2, varscan2
- ARHGAP29 | c.3431C>T p.S1144L | Missense Mutation (SNP) | VAF 50/128 reads (39%) | SIFT tolerated (0.1); PolyPhen possibly damaging (0.726); catalogued as COSV99557827; called by muse, mutect2, varscan2
- ARHGAP29 | c.1694G>A p.R565Q | Missense Mutation (SNP) | VAF 51/139 reads (37%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.475); catalogued as rs747148271, COSV99557828; called by muse, mutect2, varscan2
- ARHGAP29 | c.873G>C p.Q291H | Missense Mutation (SNP) | VAF 43/132 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.976); catalogued as COSV99557829; called by muse, mutect2, varscan2
- ARHGAP6 | c.2542G>A p.D848N (on ENST00000337414 / NM_013427.3; = p.D645N on NM_013423.3) | Missense Mutation (SNP) | VAF 12/22 reads (55%) | SIFT tolerated, low confidence (0.13); PolyPhen possibly damaging (0.709); catalogued as rs1194810934, COSV100272595; called by muse, mutect2, varscan2
- ARHGAP6 | c.584C>T p.S195F | Missense Mutation (SNP) | VAF 23/54 reads (43%) | SIFT deleterious (0); PolyPhen benign (0.007); catalogued as COSV100497512; called by muse, mutect2, varscan2
- ARHGEF12 | c.1637A>T p.Y546F | Missense Mutation (SNP) | VAF 34/44 reads (77%) | SIFT tolerated (0.18); PolyPhen benign (0.401); catalogued as COSV100754766, COSV63105676; called by muse, mutect2, varscan2
- ARHGEF15 | c.98C>T p.S33F | Missense Mutation (SNP) | VAF 47/104 reads (45%) | SIFT deleterious, low confidence (0); PolyPhen benign (0); catalogued as COSV100730231, COSV62724826; called by muse, mutect2, varscan2
- ARHGEF15 | c.1964C>T p.S655L | Missense Mutation (SNP) | VAF 207/553 reads (37%) | SIFT tolerated (0.2); PolyPhen benign (0.043); catalogued as rs867056869, COSV62725961; called by muse, mutect2, varscan2
- ARHGEF16 | c.1050C>A p.H350Q | Missense Mutation (SNP) | VAF 43/75 reads (57%) | SIFT deleterious (0); PolyPhen benign (0.098); catalogued as COSV101000383; called by muse, mutect2, varscan2
- ARHGEF16 | c.1051A>C p.K351Q | Missense Mutation (SNP) | VAF 42/76 reads (55%) | SIFT tolerated (1); PolyPhen benign (0.015); catalogued as COSV101000385; called by muse, mutect2, varscan2
- ARL4A | c.50C>T p.S17L | Missense Mutation (SNP) | VAF 74/183 reads (40%) | SIFT tolerated (0.24); PolyPhen benign (0.186); catalogued as COSV100775897; called by muse, mutect2, varscan2
- ARMC4 | c.2220G>A p.W740* | Nonsense Mutation (SNP) | VAF 81/230 reads (35%) | catalogued as rs867142532, COSV59457421; called by muse, mutect2, varscan2
- ARMC5 | c.782C>T p.A261V | Missense Mutation (SNP) | VAF 21/53 reads (40%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.831); catalogued as rs1299191579, COSV99192385; called by muse, varscan2
- ARNTL2 | c.839G>A p.R280Q | Missense Mutation (SNP) | VAF 46/125 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs754017219, COSV53826995; called by muse, mutect2, varscan2
- ARSF | c.1762G>A p.E588K | Missense Mutation (SNP) | VAF 11/33 reads (33%) | SIFT tolerated, low confidence (0.33); PolyPhen benign (0.003); catalogued as COSV100839454; called by muse, mutect2, varscan2
- ARSL | c.662C>T p.P221L | Missense Mutation (SNP) | VAF 31/69 reads (45%) | SIFT tolerated (0.31); PolyPhen benign (0.007); catalogued as COSV101140449; called by muse, mutect2, varscan2
- ARX | c.958G>A p.E320K | Missense Mutation (SNP) | VAF 10/17 reads (59%) | SIFT tolerated (0.06); PolyPhen benign (0.053); catalogued as COSV100984043; called by muse, mutect2, varscan2
- ASB12 | c.274C>T p.L92F | Missense Mutation (SNP) | VAF 13/44 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1161137545, COSV100744639; called by muse, mutect2, varscan2
- ASB15 | c.1028C>T p.S343F | Missense Mutation (SNP) | VAF 135/274 reads (49%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.866); catalogued as COSV51927921, COSV99306356; called by mutect2, varscan2
- ASB16 | c.497G>A p.G166E | Missense Mutation (SNP) | VAF 42/97 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as COSV99518795; called by muse, mutect2, varscan2
- ASCL1 | c.569C>T p.S190L | Missense Mutation (SNP) | VAF 39/96 reads (41%) | SIFT deleterious (0.02); PolyPhen benign (0.011); catalogued as rs780932953, COSV99901932; called by muse, mutect2, varscan2
- ASIC3 | c.1288G>A p.E430K | Missense Mutation (SNP) | VAF 54/188 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as COSV99876753; called by muse, mutect2, varscan2
- ASIC4 | c.1033G>A p.G345S (on ENST00000347842 / NM_182847.3; = p.G364S on NM_018674.6) | Missense Mutation (SNP) | VAF 50/106 reads (47%) | SIFT tolerated (0.28); PolyPhen benign (0.07); catalogued as rs1411392933, COSV99704795; called by muse, mutect2, varscan2
- ASMTL | c.1126T>C p.F376L | Missense Mutation (SNP) | VAF 154/363 reads (42%) | SIFT tolerated (0.71); PolyPhen benign (0.001); catalogued as COSV101187722; called by muse, mutect2, varscan2
- ASS1 | c.475G>A p.D159N | Missense Mutation (SNP) | VAF 40/56 reads (71%) | SIFT deleterious (0.03); PolyPhen benign (0.093); catalogued as COSV100752565; called by muse, mutect2, varscan2
- ASTN1 | c.1504G>A p.E502K | Missense Mutation (SNP) | VAF 285/710 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (0.97); catalogued as rs866639170, COSV56061286; called by muse, mutect2, varscan2
- ASXL3 | c.1512G>A p.M504I | Missense Mutation (SNP) | VAF 13/34 reads (38%) | SIFT tolerated, low confidence (0.37); PolyPhen benign (0); catalogued as COSV52460067; called by muse, mutect2, varscan2
- ASXL3 | c.5081C>T p.P1694L | Missense Mutation (SNP) | VAF 27/106 reads (25%) | SIFT deleterious, low confidence (0.04); PolyPhen benign (0); catalogued as rs377243058; called by muse, mutect2, varscan2
- ASZ1 | c.235G>A p.G79R | Missense Mutation (SNP) | VAF 33/101 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99497856; called by muse, mutect2, varscan2
- ATAD3C | c.1082C>T p.S361F | Missense Mutation (SNP) | VAF 5/9 reads (56%) | SIFT deleterious (0); PolyPhen possibly damaging (0.519); catalogued as rs1475724194, COSV101112593; called by muse, mutect2, varscan2
- ATCAY | c.976G>A p.E326K | Missense Mutation (SNP) | VAF 13/48 reads (27%) | SIFT deleterious (0.04); PolyPhen benign (0.039); catalogued as COSV100008577; called by muse, mutect2, varscan2
- ATG16L1 | c.141T>A p.D47E | Missense Mutation (SNP) | VAF 28/93 reads (30%) | SIFT tolerated (0.12); PolyPhen probably damaging (0.999); catalogued as rs1244860169, COSV100731284; called by muse, mutect2, varscan2
- ATG16L1 | c.142C>A p.L48I | Missense Mutation (SNP) | VAF 28/93 reads (30%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.549); catalogued as COSV100731285; called by muse, mutect2, varscan2
- ATG4A | c.664C>T p.P222S | Missense Mutation (SNP) | VAF 131/410 reads (32%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.679); catalogued as COSV58967491; called by muse, mutect2, varscan2
- ATP10A | c.3395C>T p.S1132L | Missense Mutation (SNP) | VAF 19/45 reads (42%) | SIFT deleterious (0); PolyPhen possibly damaging (0.656); catalogued as COSV100791008; called by muse, mutect2, varscan2
- ATP10B | c.652G>T p.V218F | Missense Mutation (SNP) | VAF 91/145 reads (63%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.925); catalogued as COSV100469210; called by muse, mutect2, varscan2
- ATP10D | c.2429C>T p.S810F | Missense Mutation (SNP) | VAF 10/118 reads (8%) | SIFT deleterious (0.01); PolyPhen benign (0.213); catalogued as rs76810881, COSV99905365; called by muse, mutect2
- ATP11C | c.466G>A p.E156K | Missense Mutation (SNP) | VAF 109/245 reads (44%) | SIFT deleterious (0); PolyPhen probably damaging (0.977); catalogued as rs759371950, COSV100557651; called by muse, mutect2, varscan2
- ATP13A5 | c.2720A>C p.K907T | Missense Mutation (SNP) | VAF 111/268 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (0.984); catalogued as COSV100664911; called by muse, mutect2, varscan2
- ATP13A5 | c.2071C>T p.L691F | Missense Mutation (SNP) | VAF 90/247 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100664912; called by muse, mutect2, varscan2
- ATP1A2 | c.1471C>T p.H491Y | Missense Mutation (SNP) | VAF 35/98 reads (36%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.996); catalogued as COSV100767698; called by muse, mutect2, varscan2
- ATP1A4 | c.1448C>T p.P483L | Missense Mutation (SNP) | VAF 55/163 reads (34%) | SIFT tolerated (0.05); PolyPhen benign (0.033); catalogued as COSV100927447, COSV63628166; called by muse, mutect2, varscan2
- ATP2B3 | c.2434G>A p.G812S | Missense Mutation (SNP) | VAF 45/98 reads (46%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.851); catalogued as COSV99683688; called by muse, mutect2, varscan2
- ATP2B3 | c.3617C>T p.S1206F | Missense Mutation (SNP) | VAF 49/106 reads (46%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.11); catalogued as rs1226016643, COSV54842895; called by muse, mutect2, varscan2
- ATP2C2 | c.856C>T p.P286S | Missense Mutation (SNP) | VAF 27/53 reads (51%) | SIFT deleterious (0); PolyPhen probably damaging (0.923); catalogued as COSV99297676; called by muse, mutect2, varscan2
- ATP7A | c.1771G>A p.G591R | Missense Mutation (SNP) | VAF 238/552 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100430510; called by muse, mutect2, varscan2
- ATP8B3 | c.3604T>A p.F1202I | Missense Mutation (SNP) | VAF 8/30 reads (27%) | SIFT tolerated (0.29); PolyPhen benign (0); catalogued as COSV100034220; called by muse, mutect2, varscan2
- ATP9A | c.2582C>T p.S861F | Missense Mutation (SNP) | VAF 18/46 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV58771809; called by muse, varscan2
- ATP9A | c.208C>T p.P70S | Missense Mutation (SNP) | VAF 37/86 reads (43%) | SIFT deleterious (0); PolyPhen possibly damaging (0.682); catalogued as rs1269052180, COSV100124566; called by muse, mutect2, varscan2
- ATR | c.6562C>T p.P2188S | Missense Mutation (SNP) | VAF 83/202 reads (41%) | SIFT tolerated (0.43); PolyPhen benign (0.018); catalogued as COSV100637881; called by muse, mutect2, varscan2
- ATRX | c.538C>T p.H180Y | Missense Mutation (SNP) | VAF 76/197 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (0.95); catalogued as COSV100969483; called by muse, mutect2, varscan2
- ATXN1 | c.1010C>G p.P337R | Missense Mutation (SNP) | VAF 44/121 reads (36%) | SIFT deleterious (0.03); PolyPhen benign (0.121); catalogued as COSV99785682; called by muse, mutect2, varscan2
- ATXN1 | c.800C>T p.P267L | Missense Mutation (SNP) | VAF 14/33 reads (42%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.997); catalogued as COSV99785683; called by muse, mutect2, varscan2
- AUTS2 | c.3194C>T p.S1065F | Missense Mutation (SNP) | VAF 15/48 reads (31%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.904); catalogued as COSV100715782; called by muse, mutect2, varscan2
- AXDND1 | c.136C>T p.R46C | Missense Mutation (SNP) | VAF 32/100 reads (32%) | SIFT tolerated (0.18); PolyPhen benign (0.005); catalogued as rs192778181, COSV62648232; called by muse, mutect2, varscan2
- AXDND1 | c.2115G>A p.M705I | Missense Mutation (SNP) | VAF 42/87 reads (48%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.971); catalogued as COSV62642676; called by muse, mutect2, varscan2
- B3GALT1 | c.232C>T p.P78S | Missense Mutation (SNP) | VAF 35/100 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100002584; called by muse, mutect2, varscan2
- B3GNT3 | c.901G>A p.G301S | Missense Mutation (SNP) | VAF 104/250 reads (42%) | SIFT deleterious (0.03); PolyPhen probably damaging (1); catalogued as COSV100427535; called by muse, mutect2, varscan2
- BAHD1 | c.2216C>T p.P739L | Missense Mutation (SNP) | VAF 64/178 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1228538131, COSV100086921; called by muse, varscan2
- BAIAP3 | c.1018G>A p.D340N | Missense Mutation (SNP) | VAF 20/46 reads (43%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.86); catalogued as COSV100181216; called by muse, mutect2, varscan2
- BATF3 | c.137G>A p.R46Q | Missense Mutation (SNP) | VAF 44/125 reads (35%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.997); catalogued as rs746911349, COSV54659082; called by muse, mutect2, varscan2
- BBS9 | c.1087C>T p.P363S | Missense Mutation (SNP) | VAF 24/58 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV54165081, COSV99627049; called by muse, mutect2, varscan2
- BCAR3 | c.248C>T p.S83L | Missense Mutation (SNP) | VAF 22/54 reads (41%) | SIFT deleterious (0.04); PolyPhen benign (0.001); catalogued as rs370836321, COSV99550485; called by muse, mutect2, varscan2
- BCL11B | c.367G>A p.E123K | Missense Mutation (SNP) | VAF 50/78 reads (64%) | SIFT deleterious (0.01); PolyPhen benign (0.191); catalogued as COSV61735288; called by muse, mutect2, varscan2
- BCL2L12 | c.422C>T p.S141F | Missense Mutation (SNP) | VAF 45/130 reads (35%) | SIFT deleterious, low confidence (0.03); PolyPhen possibly damaging (0.466); catalogued as rs972656772, COSV99880954; called by muse, mutect2, varscan2
- BCLAF3 | c.1583T>A p.L528* | Nonsense Mutation (SNP) | VAF 60/163 reads (37%) | catalogued as COSV100503246; called by muse, mutect2, varscan2
- BCOR | c.2722G>A p.D908N | Missense Mutation (SNP) | VAF 55/115 reads (48%) | SIFT tolerated (0.06); PolyPhen benign (0.403); catalogued as COSV100653065; called by muse, mutect2, varscan2
- BDNF | c.562C>T p.P188S | Missense Mutation (SNP) | VAF 116/171 reads (68%) | SIFT tolerated (0.27); PolyPhen benign (0.084); catalogued as COSV59233355; called by muse, mutect2, varscan2
- BDP1 | c.6128C>T p.S2043F | Missense Mutation (SNP) | VAF 93/250 reads (37%) | SIFT deleterious (0.03); PolyPhen benign (0.099); catalogued as COSV100702872; called by muse, mutect2, varscan2
- BEND2 | c.1676G>A p.G559E | Missense Mutation (SNP) | VAF 55/141 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV101191895; called by muse, mutect2, varscan2
- BEND6 | c.758G>A p.R253K | Missense Mutation (SNP) | VAF 27/83 reads (33%) | SIFT tolerated (0.43); PolyPhen probably damaging (0.982); catalogued as COSV100876795; called by muse, mutect2, varscan2
- BEST4 | c.1037C>T p.P346L | Missense Mutation (SNP) | VAF 41/137 reads (30%) | SIFT tolerated (0.17); PolyPhen benign (0.028); catalogued as COSV64733818; called by muse, mutect2, varscan2
- BFAR | c.1019C>T p.P340L | Missense Mutation (SNP) | VAF 82/187 reads (44%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs1396874758, COSV55493449; called by muse, mutect2, varscan2
- BHLHE40 | c.644C>T p.P215L | Missense Mutation (SNP) | VAF 34/83 reads (41%) | SIFT tolerated (0.61); PolyPhen benign (0); catalogued as COSV99848003; called by muse, mutect2, varscan2
- BICRA | c.2846C>T p.P949L | Missense Mutation (SNP) | VAF 13/40 reads (33%) | SIFT deleterious (0.02); PolyPhen benign (0.001); catalogued as COSV67603997; called by muse, mutect2, varscan2
- BLNK | c.1011G>A p.Q337= | Splice Region (SNP) | VAF 69/193 reads (36%) | catalogued as COSV99813732; called by muse, mutect2, varscan2
- BMP10 | c.536G>A p.G179E | Missense Mutation (SNP) | VAF 20/65 reads (31%) | SIFT tolerated (0.64); PolyPhen benign (0.003); catalogued as COSV99770346; called by muse, mutect2, varscan2
- BMP2 | c.505C>T p.H169Y | Missense Mutation (SNP) | VAF 37/97 reads (38%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.903); catalogued as COSV101122066; called by muse, mutect2, varscan2
- BMP5 | c.970C>T p.Q324* | Nonsense Mutation (SNP) | VAF 75/208 reads (36%) | catalogued as rs866515989, COSV100895840; called by muse, mutect2, varscan2
- BMPER | c.1012C>T p.P338S | Missense Mutation (SNP) | VAF 18/48 reads (38%) | SIFT tolerated (0.19); PolyPhen benign (0.04); catalogued as COSV99779248; called by muse, mutect2, varscan2
- BMS1 | c.2804T>A p.I935N | Missense Mutation (SNP) | VAF 23/63 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV100996605; called by muse, mutect2, varscan2
- BNC1 | c.1999C>T p.P667S | Missense Mutation (SNP) | VAF 44/106 reads (42%) | SIFT deleterious (0.02); PolyPhen benign (0.014); catalogued as rs867490182, COSV61757522; called by muse, mutect2, varscan2
- BNC1 | c.446G>A p.G149E | Missense Mutation (SNP) | VAF 39/123 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV100597018; called by muse, mutect2, varscan2
- BNIP5 | c.1570G>A p.G524R | Missense Mutation (SNP) | VAF 72/162 reads (44%) | SIFT tolerated (0.19); PolyPhen probably damaging (0.914); catalogued as COSV101465128; called by muse, varscan2
- BOLL | c.719C>T p.S240L | Missense Mutation (SNP) | VAF 16/48 reads (33%) | SIFT deleterious (0.02); PolyPhen benign (0.058); catalogued as rs1200870892, COSV99986952; called by muse, mutect2, varscan2
- BPTF | c.7300C>T p.H2434Y | Missense Mutation (SNP) | VAF 14/39 reads (36%) | SIFT tolerated, low confidence (1); PolyPhen benign (0.062); catalogued as COSV100074429; called by muse, mutect2, varscan2
- BRCC3 | c.262G>A p.D88N | Missense Mutation (SNP) | VAF 51/119 reads (43%) | SIFT deleterious (0); PolyPhen possibly damaging (0.859); catalogued as COSV100341506; called by muse, mutect2, varscan2
- BRD1 | c.2443C>T p.P815S (on ENST00000216267 / NM_001349940.1; = p.P946S on NM_001304808.3) | Missense Mutation (SNP) | VAF 45/105 reads (43%) | SIFT deleterious (0.05); PolyPhen benign (0.324); catalogued as COSV99349441; called by muse, mutect2, varscan2
- BRPF1 | c.2672C>T p.S891L | Missense Mutation (SNP) | VAF 69/153 reads (45%) | SIFT deleterious (0); PolyPhen possibly damaging (0.749); catalogued as COSV100121149; called by muse, mutect2, varscan2
- BSN | c.9446C>T p.S3149L | Missense Mutation (SNP) | VAF 38/97 reads (39%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.485); catalogued as rs755682920, COSV99607757; called by muse, mutect2, varscan2
- BTNL8 | c.1393G>A p.E465K | Missense Mutation (SNP) | VAF 78/97 reads (80%) | SIFT tolerated (0.83); PolyPhen benign (0.009); catalogued as COSV99180444, COSV99180473; called by muse, mutect2, varscan2
- C12orf29 | c.3G>A p.M1? | Translation Start Site (SNP) | VAF 7/17 reads (41%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.805); catalogued as rs1303683812, COSV100795065; called by muse, mutect2, varscan2
- C14orf39 | c.501G>A p.M167I | Missense Mutation (SNP) | VAF 34/44 reads (77%) | SIFT tolerated (0.13); PolyPhen benign (0.121); catalogued as COSV100407396, COSV58782313; called by muse, mutect2, varscan2
- C15orf39 | c.1460C>T p.P487L | Missense Mutation (SNP) | VAF 30/85 reads (35%) | SIFT tolerated (0.14); PolyPhen benign (0.007); catalogued as COSV100641251; called by muse, mutect2, varscan2
- C1RL | c.952C>T p.P318S | Missense Mutation (SNP) | VAF 59/141 reads (42%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.93); catalogued as COSV99864524; called by muse, mutect2, varscan2
- C1orf105 | c.267G>A p.M89I | Missense Mutation (SNP) | VAF 33/81 reads (41%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs867969720, COSV62959341; called by muse, mutect2, varscan2
- C1orf50 | c.398C>T p.S133F | Missense Mutation (SNP) | VAF 49/158 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV65308089; called by muse, mutect2, varscan2
- C2CD3 | c.2842C>T p.R948* | Nonsense Mutation (SNP) | VAF 55/84 reads (65%) | catalogued as rs1437215284, COSV58089808; called by muse, mutect2, varscan2
- C2CD6 | c.262A>T p.S88C | Missense Mutation (SNP) | VAF 48/178 reads (27%) | SIFT deleterious (0); PolyPhen possibly damaging (0.891); catalogued as COSV99632332; called by muse, mutect2, varscan2
- C2orf16 | c.1427G>A p.R476K | Missense Mutation (SNP) | VAF 34/89 reads (38%) | SIFT tolerated (0.83); PolyPhen benign (0.015); catalogued as COSV101284359; called by muse, mutect2, varscan2
- C2orf78 | c.1258A>G p.N420D | Missense Mutation (SNP) | VAF 21/53 reads (40%) | SIFT tolerated (0.11); PolyPhen benign (0.213); catalogued as COSV101280938; called by muse, mutect2, varscan2
- C2orf78 | c.2300C>T p.P767L | Missense Mutation (SNP) | VAF 30/81 reads (37%) | SIFT tolerated (0.07); PolyPhen benign (0.006); catalogued as COSV101280939; called by muse, mutect2, varscan2
- C5AR1 | c.1048G>A p.V350M | Missense Mutation (SNP) | VAF 17/41 reads (41%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.878); catalogued as rs367719223; called by muse, mutect2, varscan2
- C7 | c.194G>A p.G65E | Missense Mutation (SNP) | VAF 31/82 reads (38%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.613); catalogued as COSV57472567; called by muse, mutect2, varscan2
- C8orf34 | c.1081G>A p.E361K | Missense Mutation (SNP) | VAF 47/127 reads (37%) | SIFT deleterious (0.02); PolyPhen benign (0.122); catalogued as COSV61379409; called by muse, mutect2, varscan2
- C8orf76 | c.608C>T p.S203F | Missense Mutation (SNP) | VAF 54/85 reads (64%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.568); catalogued as COSV99414906; called by muse, mutect2, varscan2
- C9 | c.964G>A p.D322N | Missense Mutation (SNP) | VAF 48/129 reads (37%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.946); catalogued as rs879179423, COSV99661899; called by muse, mutect2, varscan2
- C9orf64 | c.845C>T p.S282L | Missense Mutation (SNP) | VAF 44/60 reads (73%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs753523523, COSV100123515; called by muse, mutect2, varscan2
- C9orf85 | c.19A>G p.N7D | Missense Mutation (SNP) | VAF 103/165 reads (62%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.985); catalogued as COSV58253578; called by muse, mutect2, varscan2
- CACNA1C | c.4706C>T p.A1569V | Missense Mutation (SNP) | VAF 56/154 reads (36%) | SIFT deleterious (0); PolyPhen benign (0.411); catalogued as COSV100217102; called by muse, mutect2, varscan2
- CACNA1E | c.3803C>T p.T1268I | Missense Mutation (SNP) | VAF 24/83 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.987); catalogued as COSV100701630; called by muse, mutect2, varscan2
- CACNA1F | c.4931A>C p.E1644A | Missense Mutation (SNP) | VAF 8/33 reads (24%) | SIFT tolerated (0.12); PolyPhen benign (0); catalogued as COSV100544555; called by muse, mutect2, varscan2
- CACNA1G | c.3244G>A p.E1082K | Missense Mutation (SNP) | VAF 7/22 reads (32%) | SIFT tolerated (0.07); PolyPhen benign (0.003); catalogued as rs1171673151, COSV61730518; called by muse, mutect2, varscan2
- CACNA1I | c.4546G>A p.E1516K | Missense Mutation (SNP) | VAF 66/191 reads (35%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.852); catalogued as COSV100359680; called by muse, mutect2, varscan2
- CACNB4 | c.1117G>A p.E373K | Missense Mutation (SNP) | VAF 15/44 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (0.987); catalogued as rs1374921337, COSV52390751, COSV52394751; called by muse, mutect2, varscan2
- CADPS2 | c.2731T>C p.F911L | Missense Mutation (SNP) | VAF 15/41 reads (37%) | SIFT deleterious (0.04); PolyPhen benign (0.144); catalogued as COSV100461613; called by muse, mutect2, varscan2
- CADPS2 | c.1651G>A p.G551S | Missense Mutation (SNP) | VAF 10/37 reads (27%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.633); catalogued as rs780685347, COSV100461619; called by muse, mutect2, varscan2
- CALR | c.716C>T p.P239L | Missense Mutation (SNP) | VAF 25/58 reads (43%) | SIFT deleterious (0.01); PolyPhen benign (0.432); catalogued as COSV100330535; called by muse, mutect2, varscan2
- CAMK1D | c.715G>A p.E239K | Missense Mutation (SNP) | VAF 40/101 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV66620544; called by muse, mutect2, varscan2
- CAMK4 | c.551C>T p.A184V | Missense Mutation (SNP) | VAF 39/66 reads (59%) | SIFT deleterious (0); PolyPhen probably damaging (0.965); catalogued as COSV99998660; called by muse, mutect2, varscan2
- CAMSAP2 | c.1579C>T p.H527Y (on ENST00000236925 / NM_001297707.2; = p.H516Y on NM_203459.3) | Missense Mutation (SNP) | VAF 41/114 reads (36%) | SIFT tolerated (1); PolyPhen benign (0.129); catalogued as COSV99373049; called by muse, mutect2, varscan2
- CAPN11 | c.1552G>A p.E518K | Missense Mutation (SNP) | VAF 42/115 reads (37%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.659); catalogued as rs770920597, COSV101291866; called by muse, mutect2, varscan2
- CAPN13 | c.1258G>A p.E420K | Missense Mutation (SNP) | VAF 24/66 reads (36%) | SIFT tolerated (0.36); PolyPhen benign (0.003); catalogued as COSV54435331; called by muse, varscan2
- CAPZA3 | c.350T>A p.L117Q | Missense Mutation (SNP) | VAF 46/95 reads (48%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.966); catalogued as COSV99856074; called by muse, mutect2, varscan2
- CARD6 | c.1562C>T p.P521L | Missense Mutation (SNP) | VAF 60/159 reads (38%) | SIFT deleterious (0.01); PolyPhen benign (0); catalogued as rs201669477, COSV54569460; called by muse, mutect2, varscan2
- CASC3 | c.580C>T p.R194* | Nonsense Mutation (SNP) | VAF 28/86 reads (33%) | catalogued as rs370981426, COSV99229585; called by muse, mutect2, varscan2
- CASC3 | c.1216C>T p.R406W | Missense Mutation (SNP) | VAF 70/183 reads (38%) | SIFT deleterious, low confidence (0.01); PolyPhen probably damaging (0.976); catalogued as rs777883693, COSV99229589; called by muse, mutect2, varscan2
- CASKIN2 | c.800C>T p.S267F | Missense Mutation (SNP) | VAF 41/84 reads (49%) | SIFT deleterious (0); PolyPhen possibly damaging (0.897); catalogued as COSV100395315, COSV100395339; called by muse, mutect2, varscan2
- CASP8AP2 | c.2864C>T p.S955F | Missense Mutation (SNP) | VAF 8/21 reads (38%) | SIFT deleterious (0); PolyPhen benign (0.179); catalogued as rs1300714470, COSV99386882; called by muse, mutect2, varscan2
- CATSPERD | c.1078G>A p.A360T | Missense Mutation (SNP) | VAF 40/92 reads (43%) | SIFT tolerated (0.65); PolyPhen benign (0.012); catalogued as COSV58466371; called by muse, mutect2, varscan2
- CATSPERD | c.1645G>A p.D549N | Missense Mutation (SNP) | VAF 46/112 reads (41%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.808); catalogued as rs191427801; called by muse, mutect2, varscan2
- CAV3 | c.337G>A p.E113K | Missense Mutation (SNP) | VAF 36/68 reads (53%) | SIFT tolerated (0.18); PolyPhen benign (0.061); catalogued as rs921802744, COSV100373086; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- CBLB | c.2723C>T p.P908L | Missense Mutation (SNP) | VAF 44/96 reads (46%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.997); catalogued as COSV99913001; called by muse, varscan2
- CBY2 | c.169G>A p.E57K | Missense Mutation (SNP) | VAF 12/27 reads (44%) | SIFT deleterious, low confidence (0.01); PolyPhen probably damaging (0.994); catalogued as COSV60118177; called by muse, mutect2
- CBY2 | c.574G>A p.E192K | Missense Mutation (SNP) | VAF 13/84 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as rs1244718492, COSV60118565; called by muse, mutect2, varscan2
- CCDC102A | c.1249G>A p.E417K | Missense Mutation (SNP) | VAF 8/24 reads (33%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.997); catalogued as COSV99264971; called by muse, mutect2, varscan2
- CCDC136 | c.3337C>T p.P1113S | Missense Mutation (SNP) | VAF 34/56 reads (61%) | SIFT deleterious (0.05); PolyPhen benign (0.066); catalogued as COSV99922397; called by muse, mutect2, varscan2
- CCDC141 | c.3610G>A p.E1204K | Missense Mutation (SNP) | VAF 30/92 reads (33%) | SIFT deleterious (0.02); PolyPhen benign (0.093); catalogued as rs914187336, COSV55370770; called by muse, mutect2, varscan2
- CCDC141 | c.2876G>A p.R959K | Missense Mutation (SNP) | VAF 22/65 reads (34%) | SIFT tolerated (1); PolyPhen benign (0.005); catalogued as rs756274985, COSV99836466; called by muse, mutect2
- CCDC141 | c.2875A>T p.R959W | Missense Mutation (SNP) | VAF 22/65 reads (34%) | SIFT deleterious (0); PolyPhen possibly damaging (0.882); catalogued as COSV55368248, COSV99836467; called by muse, mutect2
- CCDC144A | c.271G>A p.G91S | Missense Mutation (SNP) | VAF 103/278 reads (37%) | SIFT deleterious, low confidence (0.02); PolyPhen possibly damaging (0.662); catalogued as COSV100501989; called by muse, mutect2, varscan2
- CCDC144A | c.1687C>T p.P563S | Missense Mutation (SNP) | VAF 8/26 reads (31%) | SIFT tolerated (0.4); PolyPhen benign (0.438); catalogued as rs1307939550; called by muse, mutect2, varscan2
- CCDC158 | c.2968C>T p.P990S | Missense Mutation (SNP) | VAF 49/74 reads (66%) | SIFT tolerated (0.62); PolyPhen benign (0.23); catalogued as COSV66357318; called by muse, mutect2, varscan2
- CCDC180 | c.4810G>A p.A1604T | Missense Mutation (SNP) | VAF 65/84 reads (77%) | SIFT deleterious (0); PolyPhen possibly damaging (0.54); catalogued as COSV100826624; called by muse, mutect2, varscan2
- CCDC40 | c.730T>A p.F244I | Missense Mutation (SNP) | VAF 36/89 reads (40%) | SIFT deleterious (0.01); PolyPhen benign (0.086); catalogued as COSV99481548; called by muse, mutect2, varscan2
- CCDC6 | c.1360C>T p.P454S | Missense Mutation (SNP) | VAF 33/100 reads (33%) | SIFT tolerated, low confidence (0.23); PolyPhen benign (0.018); catalogued as rs534545668, COSV99569293; called by muse, mutect2, varscan2
- CCDC7 | c.4028C>T p.S1343L | Missense Mutation (SNP) | VAF 22/54 reads (41%) | SIFT tolerated, low confidence (0.06); PolyPhen probably damaging (0.988); catalogued as rs761341812, COSV56539494; called by muse, mutect2, varscan2
- CCDC9 | c.226C>T p.P76S | Missense Mutation (SNP) | VAF 52/141 reads (37%) | SIFT tolerated (0.24); PolyPhen benign (0.056); catalogued as COSV55721171; called by muse, mutect2, varscan2
- CCL17 | c.225C>A p.D75E | Missense Mutation (SNP) | VAF 19/77 reads (25%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.858); catalogued as COSV99537140; called by muse, mutect2, varscan2
- CCNB3 | c.3325G>A p.E1109K | Missense Mutation (SNP) | VAF 12/22 reads (55%) | SIFT tolerated (0.1); PolyPhen benign (0.035); catalogued as COSV52073291; called by muse, mutect2, varscan2
- CCNT1 | c.1004T>A p.L335Q | Missense Mutation (SNP) | VAF 44/101 reads (44%) | SIFT tolerated (0.19); PolyPhen benign (0.272); catalogued as COSV99980620; called by muse, varscan2
- CCR8 | c.1043C>T p.S348F | Missense Mutation (SNP) | VAF 38/82 reads (46%) | SIFT deleterious (0.01); PolyPhen benign (0.007); catalogued as COSV100413043; called by muse, mutect2, varscan2
- CCT8L2 | c.775G>A p.A259T | Missense Mutation (SNP) | VAF 58/154 reads (38%) | SIFT tolerated (0.1); PolyPhen benign (0.105); catalogued as COSV63464208; called by muse, mutect2, varscan2
- CD101 | c.2431A>G p.S811G | Missense Mutation (SNP) | VAF 26/86 reads (30%) | SIFT tolerated (0.09); PolyPhen benign (0.298); catalogued as COSV99869337; called by muse, mutect2, varscan2
- CD109 | c.3161C>G p.T1054S | Missense Mutation (SNP) | VAF 28/85 reads (33%) | SIFT tolerated (0.24); PolyPhen benign (0.179); catalogued as rs141815508, COSV54645358; called by muse, mutect2, varscan2
- CD163 | c.3146C>T p.S1049L | Missense Mutation (SNP) | VAF 40/116 reads (34%) | SIFT tolerated (0.35); PolyPhen benign (0.003); catalogued as COSV100775746; called by muse, mutect2, varscan2
- CD163L1 | c.3695C>T p.S1232F | Missense Mutation (SNP) | VAF 36/98 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (0.939); catalogued as rs1198653440, COSV100549850; called by muse, mutect2, varscan2
- CD164L2 | c.328+2T>A p.X110_splice | Splice Site (SNP) | VAF 38/104 reads (37%) | catalogued as COSV100927585; called by muse, mutect2, varscan2
- CD164L2 | c.328+1G>A p.X110_splice | Splice Site (SNP) | VAF 38/106 reads (36%) | catalogued as COSV100927586; called by muse, mutect2, varscan2
- CD177 | c.761G>A p.G254E | Missense Mutation (SNP) | VAF 13/18 reads (72%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1247791527; called by muse, mutect2, varscan2
- CD300LB | c.444G>C p.R148S | Missense Mutation (SNP) | VAF 17/49 reads (35%) | SIFT tolerated (0.16); PolyPhen benign (0.011); catalogued as COSV100075356; called by muse, mutect2, varscan2
- CD300LB | c.127G>A p.E43K | Missense Mutation (SNP) | VAF 116/270 reads (43%) | SIFT tolerated (0.36); PolyPhen benign (0.251); catalogued as COSV58725379; called by muse, mutect2, varscan2
- CD38 | c.628G>A p.G210R | Missense Mutation (SNP) | VAF 45/66 reads (68%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99882480; called by muse, mutect2, varscan2
- CD5L | c.950G>A p.G317E | Missense Mutation (SNP) | VAF 41/104 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100941022; called by muse, mutect2, varscan2
- CD68 | c.892C>T p.Q298* | Nonsense Mutation (SNP) | VAF 24/73 reads (33%) | catalogued as COSV99548826; called by muse, mutect2, varscan2
- CD86 | c.23G>A p.G8E (on ENST00000330540 / NM_175862.5; = p.G2E on NM_006889.4) | Missense Mutation (SNP) | VAF 158/394 reads (40%) | SIFT tolerated (0.17); PolyPhen benign (0.012); catalogued as COSV100053888; called by muse, mutect2, varscan2
- CD86 | c.760C>T p.P254S (on ENST00000330540 / NM_175862.5; = p.P248S on NM_006889.4) | Missense Mutation (SNP) | VAF 37/134 reads (28%) | SIFT tolerated (0.1); PolyPhen benign (0.028); catalogued as COSV52609322; called by muse, mutect2, varscan2
- CDC45 | c.1439C>T p.S480L | Missense Mutation (SNP) | VAF 9/34 reads (26%) | SIFT tolerated (0.12); PolyPhen benign (0.107); catalogued as rs764940993, COSV54245341; called by muse, mutect2, varscan2
- CDC6 | c.707T>A p.L236* | Nonsense Mutation (SNP) | VAF 41/102 reads (40%) | catalogued as COSV99266517; called by muse, mutect2, varscan2
- CDCA7 | c.1102G>A p.E368K (on ENST00000347703 / NM_145810.3; = p.E447K on NM_031942.5) | Missense Mutation (SNP) | VAF 60/149 reads (40%) | SIFT deleterious (0.01); PolyPhen benign (0.376); catalogued as COSV100143406; called by muse, mutect2, varscan2
- CDH12 | c.131G>A p.G44E | Missense Mutation (SNP) | VAF 81/209 reads (39%) | SIFT tolerated (0.11); PolyPhen benign (0.005); catalogued as COSV101201949; called by muse, varscan2
- CDH12 | c.23C>T p.S8F | Missense Mutation (SNP) | VAF 44/119 reads (37%) | SIFT tolerated (0.7); PolyPhen benign (0); catalogued as rs1211476604, COSV66420319, COSV66423634; called by muse, varscan2
- CDH13 | c.1339G>A p.E447K | Missense Mutation (SNP) | VAF 31/79 reads (39%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.973); catalogued as COSV51791284; called by muse, mutect2, varscan2
- CDH13 | c.1628C>T p.S543F | Missense Mutation (SNP) | VAF 95/219 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV99224023; called by muse, mutect2, varscan2
- CDH18 | c.1668T>A p.F556L | Missense Mutation (SNP) | VAF 23/70 reads (33%) | SIFT deleterious (0.03); PolyPhen benign (0.253); catalogued as COSV99933192; called by muse, varscan2
- CDH19 | c.1876C>A p.L626I | Missense Mutation (SNP) | VAF 52/170 reads (31%) | SIFT tolerated (0.17); PolyPhen possibly damaging (0.681); catalogued as rs1413928670, COSV100051227, COSV50959575; called by muse, mutect2, varscan2
- CDH23 | c.580G>A p.D194N | Missense Mutation (SNP) | VAF 22/61 reads (36%) | SIFT deleterious (0); PolyPhen benign (0.071); catalogued as COSV99819781; called by muse, mutect2, varscan2
- CDH23 | c.1449+8C>T | Splice Region (SNP) | VAF 90/222 reads (41%) | catalogued as COSV99819786; called by muse, mutect2, varscan2
- CDH23 | c.2971G>A p.E991K | Missense Mutation (SNP) | VAF 10/27 reads (37%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.844); catalogued as rs551073659, COSV99819789; ClinVar: uncertain significance; called by muse, varscan2
- CDH23 | c.5416G>A p.D1806N | Missense Mutation (SNP) | VAF 33/98 reads (34%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.682); catalogued as COSV56499306; called by muse, mutect2, varscan2
- CDH26 | c.1004G>A p.G335E | Missense Mutation (SNP) | VAF 48/112 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV99722080; called by muse, mutect2, varscan2
- CDH4 | c.1195G>A p.G399R | Missense Mutation (SNP) | VAF 14/39 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV100848592; called by muse, varscan2
- CDH4 | c.1198G>A p.E400K | Missense Mutation (SNP) | VAF 14/40 reads (35%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.999); catalogued as rs370373224, COSV100848646; called by muse, varscan2
- CDH8 | c.1522G>A p.G508R | Missense Mutation (SNP) | VAF 33/127 reads (26%) | SIFT deleterious (0); PolyPhen possibly damaging (0.666); catalogued as COSV100179213, COSV54910899; called by muse, mutect2, varscan2
- CDK14 | c.527T>A p.F176Y (on ENST00000380050 / NM_001287135.2; = p.F158Y on NM_012395.3) | Missense Mutation (SNP) | VAF 27/61 reads (44%) | SIFT tolerated (0.09); PolyPhen probably damaging (0.966); catalogued as COSV99724391; called by muse, mutect2, varscan2
- CDKL4 | c.905G>A p.G302E | Missense Mutation (SNP) | VAF 60/192 reads (31%) | SIFT tolerated (0.2); PolyPhen probably damaging (0.999); catalogued as COSV66509838; called by muse, mutect2, varscan2
- CDKL5 | c.2116G>A p.D706N | Missense Mutation (SNP) | VAF 67/167 reads (40%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.722); catalogued as COSV101184154; called by muse, mutect2, varscan2
- CDKN2AIP | c.1039C>T p.P347S | Missense Mutation (SNP) | VAF 42/61 reads (69%) | SIFT tolerated (0.08); PolyPhen benign (0.003); catalogued as rs748481942, COSV100187573; called by muse, mutect2, varscan2
- CDKN2AIP | c.1040C>T p.P347L | Missense Mutation (SNP) | VAF 42/61 reads (69%) | SIFT deleterious (0.02); PolyPhen benign (0.074); catalogued as COSV100187576; called by muse, mutect2, varscan2
- CDNF | c.466G>A p.E156K | Missense Mutation (SNP) | VAF 71/195 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV101012365; called by muse, varscan2
- CDON | c.823C>T p.L275F | Missense Mutation (SNP) | VAF 28/45 reads (62%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV99700998; called by muse, mutect2, varscan2
- CEACAM20 | c.1486G>A p.E496K | Missense Mutation (SNP) | VAF 27/56 reads (48%) | SIFT tolerated (0.14); PolyPhen benign (0.16); catalogued as COSV57602979; called by muse, mutect2, varscan2
- CEACAM6 | c.480G>T p.K160N | Missense Mutation (SNP) | VAF 145/355 reads (41%) | SIFT tolerated (0.12); PolyPhen benign (0.162); catalogued as COSV99555485; called by muse, mutect2, varscan2
- CEACAM6 | c.859C>T p.P287S | Missense Mutation (SNP) | VAF 29/105 reads (28%) | SIFT deleterious (0.04); PolyPhen benign (0.042); catalogued as COSV99555487; called by muse, mutect2, varscan2
- CEACAM8 | c.504A>C p.E168D | Missense Mutation (SNP) | VAF 123/313 reads (39%) | SIFT tolerated (0.4); PolyPhen benign (0.275); catalogued as COSV99747505; called by muse, mutect2, varscan2
- CEL | c.1186C>T p.Q396* (on ENST00000673714; = p.Q393* on NM_001807.6) | Nonsense Mutation (SNP) | VAF 10/14 reads (71%) | catalogued as COSV100672343; called by mutect2, varscan2
- CEMIP | c.3583A>C p.M1195L | Missense Mutation (SNP) | VAF 21/54 reads (39%) | SIFT deleterious (0.01); PolyPhen benign (0.001); catalogued as COSV99586389; called by muse, mutect2, varscan2
- CENPF | c.5399T>A p.L1800* | Nonsense Mutation (SNP) | VAF 28/63 reads (44%) | catalogued as COSV100871600; called by muse, mutect2, varscan2
- CEP126 | c.3272C>T p.P1091L | Missense Mutation (SNP) | VAF 13/36 reads (36%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.695); catalogued as COSV99680818; called by muse, mutect2, varscan2
- CEP72 | c.1214C>T p.P405L | Missense Mutation (SNP) | VAF 31/91 reads (34%) | SIFT tolerated (0.06); PolyPhen benign (0.009); catalogued as rs1444658631, COSV99374632; called by muse, mutect2, varscan2
- CERS3 | c.1058A>C p.E353A | Missense Mutation (SNP) | VAF 14/48 reads (29%) | SIFT tolerated (0.17); PolyPhen benign (0.007); catalogued as rs1404574749, COSV99431612; called by muse, mutect2, varscan2
- CES5A | c.424G>A p.V142M | Missense Mutation (SNP) | VAF 6/30 reads (20%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.726); catalogued as rs751950787, COSV99307281; called by muse, mutect2
- CFAP20DC | c.2329C>T p.Q777* (on ENST00000482387 / NM_001351530.2; = p.Q526* on NM_198463.4 and 2 other RefSeq transcripts) | Nonsense Mutation (SNP) | VAF 28/67 reads (42%) | catalogued as rs768472036, COSV99918364; called by muse, mutect2, varscan2
- CFAP47 | c.1587G>A p.M529I | Missense Mutation (SNP) | VAF 60/156 reads (38%) | SIFT tolerated (0.44); PolyPhen benign (0.26); catalogued as rs867010439, COSV99934682; called by muse, mutect2, varscan2
- CFAP52 | c.855G>A p.K285= | Splice Region (SNP) | VAF 37/85 reads (44%) | catalogued as rs1352129023, COSV55349357; called by muse, mutect2, varscan2
- CFAP54 | c.8237T>C p.F2746S | Missense Mutation (SNP) | VAF 59/176 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV100733045; called by muse, mutect2, varscan2
- CFAP58 | c.2263G>A p.E755K | Missense Mutation (SNP) | VAF 42/107 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (0.924); catalogued as rs1314889490, COSV100866066; called by muse, mutect2, varscan2
- CFAP61 | c.1784C>T p.S595F | Missense Mutation (SNP) | VAF 35/70 reads (50%) | SIFT tolerated (0.53); PolyPhen benign (0.001); catalogued as rs1316340123, COSV99843992; called by muse, mutect2, varscan2
- CFAP65 | c.2803C>T p.Q935* | Nonsense Mutation (SNP) | VAF 6/18 reads (33%) | catalogued as COSV100444849; called by muse, mutect2, varscan2
- CFH | c.1927G>A p.E643K | Missense Mutation (SNP) | VAF 30/76 reads (39%) | SIFT tolerated (0.38); PolyPhen benign (0.322); catalogued as rs867229260, COSV66406054; called by muse, mutect2, varscan2
- CFP | c.431C>T p.P144L | Missense Mutation (SNP) | VAF 14/29 reads (48%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.673); catalogued as COSV55950319; called by muse, mutect2, varscan2
- CFTR | c.1823A>G p.E608G | Missense Mutation (SNP) | VAF 58/172 reads (34%) | SIFT tolerated (0.13); PolyPhen possibly damaging (0.879); catalogued as rs397508309, CM024233, COSV99134725; ClinVar: not provided; called by muse, mutect2, varscan2
- CFTR | c.2393C>T p.P798L | Missense Mutation (SNP) | VAF 22/70 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.93); catalogued as COSV99134728; called by muse, mutect2, varscan2
- CGNL1 | c.1042G>A p.G348R | Missense Mutation (SNP) | VAF 28/65 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (0.96); catalogued as COSV99847825; called by muse, mutect2, varscan2
- CHD5 | c.1111G>A p.D371N | Missense Mutation (SNP) | VAF 8/21 reads (38%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.554); catalogued as COSV99312995, COSV99314750; called by muse, mutect2, varscan2
- CHD7 | c.98C>T p.P33L | Missense Mutation (SNP) | VAF 13/27 reads (48%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.007); catalogued as COSV101418093, COSV101418379; called by muse, mutect2, varscan2
- CHL1 | c.625C>T p.P209S | Missense Mutation (SNP) | VAF 28/65 reads (43%) | SIFT tolerated (0.11); PolyPhen benign (0.396); catalogued as COSV99850551; called by muse, mutect2, varscan2
- CHMP4C | c.348G>A p.M116I | Missense Mutation (SNP) | VAF 21/59 reads (36%) | SIFT tolerated (0.07); PolyPhen benign (0.135); catalogued as COSV99794103; called by muse, mutect2, varscan2
- CHRM5 | c.1542G>A p.W514* | Nonsense Mutation (SNP) | VAF 29/83 reads (35%) | catalogued as rs1312353774, COSV67246933; called by muse, mutect2, varscan2
- CHRNA5 | c.824C>T p.P275L | Missense Mutation (SNP) | VAF 58/179 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100213847; called by muse, mutect2, varscan2
- CHST1 | c.31C>T p.L11F | Missense Mutation (SNP) | VAF 19/40 reads (48%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV100346113; called by muse, mutect2, varscan2
- CHST15 | c.196G>A p.E66K | Missense Mutation (SNP) | VAF 34/110 reads (31%) | SIFT tolerated (0.27); PolyPhen benign (0.003); catalogued as rs199887555, COSV60560141, COSV60560330; called by muse, mutect2, varscan2
- CIART | c.176C>G p.P59R | Missense Mutation (SNP) | VAF 88/190 reads (46%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.976); catalogued as COSV99290182; called by muse, mutect2, varscan2
- CILP2 | c.3134C>T p.A1045V | Missense Mutation (SNP) | VAF 14/26 reads (54%) | SIFT tolerated (0.13); PolyPhen benign (0.097); catalogued as COSV99364480; called by muse, mutect2, varscan2
- CIT | c.4826C>T p.T1609I | Missense Mutation (SNP) | VAF 30/72 reads (42%) | SIFT deleterious (0.01); PolyPhen benign (0.172); catalogued as COSV99948921; called by muse, mutect2, varscan2
- CIT | c.1502C>T p.S501F | Missense Mutation (SNP) | VAF 90/251 reads (36%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.556); catalogued as rs1248895144, COSV55864703; called by muse, mutect2, varscan2
- CLCA1 | c.1216G>A p.E406K | Missense Mutation (SNP) | VAF 41/67 reads (61%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.952); catalogued as COSV99322078; called by muse, mutect2, varscan2
- CLCN1 | c.582G>A p.M194I | Missense Mutation (SNP) | VAF 97/187 reads (52%) | SIFT deleterious (0); PolyPhen benign (0.354); catalogued as COSV58367101; called by muse, mutect2, varscan2
- CLCN1 | c.821G>C p.G274A | Missense Mutation (SNP) | VAF 42/154 reads (27%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as COSV100577846; called by muse, mutect2, varscan2
- CLEC3A | c.355G>A p.E119K (on ENST00000651443; = p.E110K on NM_005752.6) | Missense Mutation (SNP) | VAF 50/115 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); catalogued as rs202038528, COSV55219665, COSV55219802, COSV55220651; called by muse, mutect2, varscan2
- CLEC4M | c.238A>C p.S80R | Missense Mutation (SNP) | VAF 48/126 reads (38%) | SIFT tolerated (0.39); PolyPhen possibly damaging (0.899); catalogued as COSV99940442; called by muse, mutect2, varscan2
- CLIP1 | c.1661C>T p.S554F (on ENST00000620786 / NM_001247997.1; = p.S543F on NM_002956.2) | Missense Mutation (SNP) | VAF 118/300 reads (39%) | SIFT deleterious (0); PolyPhen possibly damaging (0.474); catalogued as COSV100211431; called by muse, mutect2, varscan2
- CLMN | c.1103C>T p.S368F | Missense Mutation (SNP) | VAF 42/59 reads (71%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.556); catalogued as rs757003520, COSV54183297; called by muse, mutect2, varscan2
- CLNK | c.770G>A p.R257K | Missense Mutation (SNP) | VAF 5/13 reads (38%) | SIFT tolerated (0.17); PolyPhen benign (0.017); catalogued as rs1300301836, COSV99904809; called by muse, mutect2, varscan2
- CLTCL1 | c.2578C>T p.P860S | Missense Mutation (SNP) | VAF 4/18 reads (22%) | SIFT deleterious (0.05); PolyPhen benign (0.031); catalogued as rs1555952442, COSV54229228, COSV99594733; called by muse, mutect2
- CLUH | c.1946C>T p.S649F (on ENST00000435359; = p.S687F on NM_015229.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 21/52 reads (40%) | SIFT deleterious (0.03); PolyPhen benign (0.079); catalogued as COSV101425672; called by muse, mutect2, varscan2
- CLVS2 | c.337C>T p.H113Y | Missense Mutation (SNP) | VAF 44/129 reads (34%) | SIFT tolerated (0.07); PolyPhen benign (0.442); catalogued as COSV99252380; called by muse, mutect2, varscan2
- CMYA5 | c.4358C>G p.S1453C | Missense Mutation (SNP) | VAF 35/68 reads (51%) | SIFT deleterious (0); PolyPhen probably damaging (0.98); catalogued as rs1314199158, COSV101483955; called by muse, mutect2, varscan2
- CMYA5 | c.9243A>T p.K3081N | Missense Mutation (SNP) | VAF 23/67 reads (34%) | SIFT deleterious (0.04); PolyPhen benign (0.024); catalogued as COSV101483958; called by muse, mutect2, varscan2
- CNN1 | c.403G>A p.G135R | Missense Mutation (SNP) | VAF 20/39 reads (51%) | SIFT deleterious (0.02); PolyPhen benign (0.114); catalogued as rs1361744211, COSV99372269; called by muse, mutect2, varscan2
- CNNM1 | c.2213G>T p.R738L | Missense Mutation (SNP) | VAF 6/14 reads (43%) | SIFT deleterious (0.04); PolyPhen benign (0.13); catalogued as rs759314624, COSV100763798; called by muse, varscan2
- CNNM2 | c.1352C>T p.T451I | Missense Mutation (SNP) | VAF 17/43 reads (40%) | SIFT deleterious (0); PolyPhen benign (0.286); catalogued as COSV100881679; called by muse, mutect2, varscan2
- CNR2 | c.515G>A p.W172* | Nonsense Mutation (SNP) | VAF 27/64 reads (42%) | catalogued as COSV100991311, COSV65692315; called by muse, mutect2, varscan2
- CNTN5 | c.1660G>A p.E554K | Missense Mutation (SNP) | VAF 49/63 reads (78%) | SIFT tolerated (0.42); PolyPhen possibly damaging (0.486); catalogued as rs1489941088, COSV54278175; called by muse, mutect2, varscan2
- CNTNAP4 | c.486G>A p.W162* | Nonsense Mutation (SNP) | VAF 35/90 reads (39%) | catalogued as COSV56666710; called by muse, mutect2, varscan2
- CNTNAP4 | c.2833G>A p.E945K | Missense Mutation (SNP) | VAF 28/96 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV56696294; called by muse, mutect2, varscan2
- CNTNAP5 | c.2995T>C p.S999P | Missense Mutation (SNP) | VAF 8/21 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.971); catalogued as rs1362393602, COSV101443217; called by mutect2, varscan2
- COBL | c.2483C>T p.P828L | Missense Mutation (SNP) | VAF 28/65 reads (43%) | SIFT tolerated (0.82); PolyPhen benign (0.053); catalogued as rs1358202964, COSV99471828; called by muse, mutect2, varscan2
- COL11A1 | c.1903G>A p.E635K | Missense Mutation (SNP) | VAF 46/114 reads (40%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.579); catalogued as COSV100615671, COSV62182509; called by muse, mutect2, varscan2
- COL11A1 | c.1127G>A p.G376E | Missense Mutation (SNP) | VAF 50/120 reads (42%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV100615672; called by muse, mutect2, varscan2
- COL11A2 | c.3143G>A p.G1048D (on ENST00000341947 / NM_080680.3; = p.G941D on NM_080679.2) | Missense Mutation (SNP) | VAF 13/31 reads (42%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV100553640; called by muse, varscan2
- COL12A1 | c.4240C>T p.R1414* | Nonsense Mutation (SNP) | VAF 30/77 reads (39%) | catalogued as COSV59392176; called by muse, mutect2, varscan2
- COL1A2 | c.890C>T p.P297L | Missense Mutation (SNP) | VAF 34/129 reads (26%) | SIFT tolerated (0.09); PolyPhen benign (0.045); catalogued as rs370146896; called by muse, mutect2, varscan2
- COL21A1 | c.2000C>T p.P667L | Missense Mutation (SNP) | VAF 15/33 reads (45%) | SIFT tolerated (0.05); PolyPhen benign (0.162); catalogued as COSV99778003; called by muse, mutect2, varscan2
- COL21A1 | c.335G>A p.G112E | Missense Mutation (SNP) | VAF 14/49 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV55156309; called by muse, mutect2, varscan2
- COL24A1 | c.3820C>T p.P1274S | Missense Mutation (SNP) | VAF 47/61 reads (77%) | SIFT tolerated (0.34); PolyPhen benign (0.16); catalogued as COSV65304546; called by muse, mutect2, varscan2
- COL24A1 | c.2311G>A p.G771S | Missense Mutation (SNP) | VAF 42/60 reads (70%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV65303353; called by muse, mutect2, varscan2
- COL2A1 | c.242C>T p.P81L | Missense Mutation (SNP) | VAF 31/80 reads (39%) | SIFT deleterious (0.05); PolyPhen benign (0.144); catalogued as COSV61532361; called by muse, mutect2, varscan2
- COL3A1 | c.718G>A p.G240R | Missense Mutation (SNP) | VAF 19/56 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs587779468, CM001090, COSV100482726; called by muse, mutect2, varscan2
- COL4A1 | c.3964C>T p.P1322S | Missense Mutation (SNP) | VAF 14/191 reads (7%) | SIFT tolerated (0.14); PolyPhen probably damaging (0.997); catalogued as rs774799679, COSV101011021; called by muse, mutect2
- COL4A1 | c.2719G>A p.D907N | Missense Mutation (SNP) | VAF 35/52 reads (67%) | SIFT tolerated (0.13); PolyPhen probably damaging (0.915); catalogued as COSV101011022; called by muse, mutect2, varscan2
- COL4A3 | c.298G>A p.G100R | Missense Mutation (SNP) | VAF 80/200 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs762282540, COSV101170118; called by muse, mutect2, varscan2
- COL4A3 | c.2881G>A p.G961R | Missense Mutation (SNP) | VAF 14/22 reads (64%) | SIFT deleterious (0); PolyPhen benign (0.437); catalogued as rs1285576172, COSV100516687; called by muse, mutect2, varscan2
- COL4A4 | c.3905C>T p.P1302L | Missense Mutation (SNP) | VAF 52/143 reads (36%) | SIFT tolerated (0.68); PolyPhen benign (0.018); catalogued as COSV100306471; called by muse, mutect2, varscan2
- COL4A4 | c.2384-1G>A p.X795_splice | Splice Site (SNP) | VAF 9/28 reads (32%) | catalogued as COSV100306472, COSV100307371; called by muse, mutect2, varscan2
- COL4A5 | c.2902G>A p.E968K | Missense Mutation (SNP) | VAF 36/122 reads (30%) | SIFT deleterious (0.01); PolyPhen benign (0.112); catalogued as COSV60355555; called by muse, mutect2, varscan2
- COL4A6 | c.3206G>A p.G1069E | Missense Mutation (SNP) | VAF 30/82 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100563154; called by muse, mutect2, varscan2
- COL5A1 | c.2630G>A p.G877E | Missense Mutation (SNP) | VAF 14/21 reads (67%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1433832312, COSV100879711; called by muse, mutect2, varscan2
- COL5A2 | c.1514C>T p.P505L | Missense Mutation (SNP) | VAF 130/303 reads (43%) | SIFT tolerated (0.1); PolyPhen benign (0.001); catalogued as rs1234716349, COSV100880107; called by muse, mutect2, varscan2
- COL5A3 | c.1066C>T p.R356W | Missense Mutation (SNP) | VAF 24/85 reads (28%) | SIFT tolerated (0.06); PolyPhen benign (0); catalogued as rs147076757; called by muse, mutect2, varscan2
- COL5A3 | c.926C>T p.S309F | Missense Mutation (SNP) | VAF 66/157 reads (42%) | SIFT tolerated (0.12); PolyPhen benign (0.136); catalogued as COSV99318434; called by muse, mutect2, varscan2
- COL6A2 | c.1088C>T p.P363L | Missense Mutation (SNP) | VAF 14/27 reads (52%) | SIFT tolerated (0.25); PolyPhen benign (0.059); catalogued as COSV100153166; called by muse, mutect2, varscan2
- COL6A6 | c.5091G>A p.M1697I | Missense Mutation (SNP) | VAF 11/28 reads (39%) | SIFT tolerated (0.34); PolyPhen benign (0.003); catalogued as COSV100650059; called by muse, mutect2, varscan2
- COL7A1 | c.7133C>T p.S2378F | Missense Mutation (SNP) | VAF 45/96 reads (47%) | SIFT deleterious (0); PolyPhen possibly damaging (0.477); catalogued as rs1411532691, COSV60395285; called by muse, mutect2, varscan2
- COL7A1 | c.3337G>A p.D1113N | Missense Mutation (SNP) | VAF 14/32 reads (44%) | SIFT tolerated (0.07); PolyPhen benign (0.015); catalogued as COSV100095483; called by muse, mutect2, varscan2
- COL9A1 | c.2398C>T p.P800S | Missense Mutation (SNP) | VAF 30/72 reads (42%) | SIFT tolerated (0.23); PolyPhen possibly damaging (0.795); catalogued as rs527945609, COSV100294356, COSV100295061; called by muse, mutect2
- COL9A3 | c.1729C>T p.R577* | Nonsense Mutation (SNP) | VAF 52/146 reads (36%) | catalogued as rs1201247953, COSV58985033; called by muse, mutect2, varscan2
- COMMD2 | c.520C>T p.H174Y | Missense Mutation (SNP) | VAF 54/130 reads (42%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.978); catalogued as COSV71946607; called by muse, mutect2, varscan2
- COQ9 | c.522-2A>G p.X174_splice | Splice Site (SNP) | VAF 19/63 reads (30%) | catalogued as COSV52646141; called by muse, mutect2, varscan2
- CORIN | c.979G>A p.G327R | Missense Mutation (SNP) | VAF 33/72 reads (46%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99903233; called by muse, mutect2, varscan2
- CORIN | c.784G>A p.E262K | Missense Mutation (SNP) | VAF 10/112 reads (9%) | SIFT tolerated (0.48); PolyPhen benign (0.205); catalogued as rs866164544, COSV56688788; called by muse, mutect2
- COX7B | c.52C>T p.Q18* | Nonsense Mutation (SNP) | VAF 48/125 reads (38%) | catalogued as COSV100968788; called by muse, mutect2, varscan2
- COX7C | c.126T>A p.C42* | Nonsense Mutation (SNP) | VAF 76/209 reads (36%) | catalogued as COSV99915176; called by muse, mutect2, varscan2
- CPA6 | c.669G>A p.M223I | Missense Mutation (SNP) | VAF 23/79 reads (29%) | SIFT tolerated (0.08); PolyPhen benign (0.003); catalogued as rs752896429, COSV52736558, COSV99913636; called by muse, mutect2, varscan2
- CPD | c.2939C>T p.S980F | Missense Mutation (SNP) | VAF 100/250 reads (40%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.949); catalogued as COSV99852628; called by muse, mutect2, varscan2
- CPD | c.3101C>T p.P1034L | Missense Mutation (SNP) | VAF 52/123 reads (42%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99852631; called by muse, mutect2, varscan2
- CPN1 | c.1300G>A p.G434R | Missense Mutation (SNP) | VAF 30/96 reads (31%) | SIFT tolerated (0.1); PolyPhen benign (0.003); catalogued as COSV100962580; called by muse, mutect2, varscan2
- CPS1 | c.463G>A p.E155K | Missense Mutation (SNP) | VAF 53/124 reads (43%) | SIFT tolerated (0.13); PolyPhen benign (0.099); catalogued as COSV99242511; called by muse, mutect2, varscan2
- CPS1 | c.2816C>T p.P939L | Missense Mutation (SNP) | VAF 37/103 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99242512; called by muse, mutect2, varscan2
- CPT2 | c.631C>T p.P211S | Missense Mutation (SNP) | VAF 31/53 reads (58%) | SIFT deleterious (0); PolyPhen probably damaging (0.987); catalogued as rs796051942, COSV53759786; called by muse, mutect2, varscan2
- CPXM1 | c.489G>A p.W163* | Nonsense Mutation (SNP) | VAF 28/76 reads (37%) | catalogued as rs763248705, COSV101013697; called by muse, mutect2, varscan2
- CR2 | c.577A>T p.K193* | Nonsense Mutation (SNP) | VAF 80/189 reads (42%) | catalogued as COSV100889560; called by muse, mutect2, varscan2
- CR2 | c.2372C>T p.P791L | Missense Mutation (SNP) | VAF 59/146 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100889561; called by muse, mutect2, varscan2
- CRAMP1 | c.1496C>T p.A499V | Missense Mutation (SNP) | VAF 33/46 reads (72%) | SIFT tolerated, low confidence (0.11); PolyPhen benign (0.001); catalogued as rs1298937487, COSV99245779; called by muse, mutect2, varscan2
- CRB1 | c.1361G>A p.G454E | Missense Mutation (SNP) | VAF 57/138 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV66330534; called by muse, mutect2, varscan2
- CRB2 | c.3409G>T p.E1137* | Nonsense Mutation (SNP) | VAF 71/88 reads (81%) | catalogued as rs1358423474, COSV100749578; called by muse, mutect2, varscan2
- CRHR1 | c.196C>T p.R66W | Missense Mutation (SNP) | VAF 24/50 reads (48%) | SIFT tolerated (0.08); PolyPhen probably damaging (0.978); catalogued as rs368605173; called by muse, mutect2, varscan2
- CRISP2 | c.250G>A p.D84N | Missense Mutation (SNP) | VAF 42/112 reads (38%) | SIFT tolerated (0.33); PolyPhen benign (0.003); catalogued as rs1472089090, COSV59253383; called by muse, mutect2, varscan2
- CRISP3 | c.539T>A p.L180H (on ENST00000371159 / NM_001368123.1; = p.L162H on NM_006061.4) | Missense Mutation (SNP) | VAF 85/236 reads (36%) | SIFT tolerated (0.17); PolyPhen benign (0.043); catalogued as COSV99538780; called by muse, mutect2, varscan2
- CRISPLD1 | c.1219C>T p.H407Y | Missense Mutation (SNP) | VAF 48/115 reads (42%) | SIFT deleterious (0.04); PolyPhen benign (0.001); catalogued as COSV100081750; called by muse, mutect2, varscan2
- CRNKL1 | c.7G>A p.A3T | Missense Mutation (SNP) | VAF 46/127 reads (36%) | SIFT tolerated, low confidence (0.06); PolyPhen benign (0); catalogued as rs1351158586, COSV99843991; called by muse, mutect2, varscan2
- CRTC2 | c.1205C>T p.S402F | Missense Mutation (SNP) | VAF 12/25 reads (48%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.854); catalogued as COSV57843957; called by muse, mutect2, varscan2
- CRYAA | c.88G>A p.G30S | Missense Mutation (SNP) | VAF 22/55 reads (40%) | SIFT tolerated (0.25); PolyPhen probably damaging (0.99); catalogued as COSV99374853; called by mutect2, varscan2
- CSAD | c.763C>T p.P255S (on ENST00000444623 / NM_001244705.2; = p.P282S on NM_015989.5) | Missense Mutation (SNP) | VAF 37/125 reads (30%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as rs200339124, COSV99914596; called by muse, mutect2, varscan2
- CSDE1 | c.1276C>T p.H426Y (on ENST00000358528 / NM_001007553.3; = p.H395Y on NM_007158.6) | Missense Mutation (SNP) | VAF 65/123 reads (53%) | SIFT deleterious (0.03); PolyPhen benign (0); catalogued as rs1396056302, COSV99794445; called by muse, mutect2, varscan2
- CSF1R | c.1511-1G>A p.X504_splice | Splice Site (SNP) | VAF 11/56 reads (20%) | catalogued as rs1164152721, COSV99641296; called by muse, mutect2, varscan2
- CSF2RA | c.725C>T p.T242I | Missense Mutation (SNP) | VAF 78/187 reads (42%) | SIFT deleterious (0); PolyPhen benign (0.145); catalogued as COSV100817596; called by muse, mutect2, varscan2
- CSGALNACT1 | c.853G>A p.E285K | Missense Mutation (SNP) | VAF 42/92 reads (46%) | SIFT tolerated (0.49); PolyPhen benign (0.168); catalogued as rs1384021592, COSV100174692; called by muse, mutect2, varscan2
- CSMD1 | c.6346C>T p.P2116S (on ENST00000520002; = p.P2115S on NM_033225.6) | Missense Mutation (SNP) | VAF 36/85 reads (42%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.996); catalogued as rs865819789, COSV59343338; called by muse, mutect2, varscan2
- CSMD1 | c.1124C>T p.S375L (on ENST00000520002; = p.S374L on NM_033225.6) | Missense Mutation (SNP) | VAF 11/35 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.952); catalogued as rs762593887, COSV68165271; called by muse, mutect2, varscan2
- CSMD2 | c.8708G>A p.R2903Q | Missense Mutation (SNP) | VAF 43/92 reads (47%) | SIFT tolerated (1); PolyPhen benign (0.086); catalogued as rs754065561, COSV53888485, COSV99587660; called by muse, mutect2, varscan2
- CSMD2 | c.5988G>A p.W1996* | Nonsense Mutation (SNP) | VAF 16/47 reads (34%) | catalogued as COSV53881000; called by muse, mutect2, varscan2
- CSMD2 | c.1949G>A p.G650E | Missense Mutation (SNP) | VAF 23/56 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs868169530, COSV53878136; called by muse, mutect2, varscan2
- CSRP3 | c.34G>A p.A12T | Missense Mutation (SNP) | VAF 39/59 reads (66%) | SIFT tolerated (0.33); PolyPhen possibly damaging (0.845); catalogued as COSV99788195; called by muse, mutect2, varscan2
- CST9 | c.340C>T p.P114S | Missense Mutation (SNP) | VAF 74/197 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.935); catalogued as COSV100980464; called by muse, mutect2, varscan2
- CSTF2 | c.346G>A p.G116R | Missense Mutation (SNP) | VAF 62/153 reads (41%) | SIFT deleterious (0); PolyPhen possibly damaging (0.833); catalogued as COSV100802931; called by muse, mutect2, varscan2
- CSTF2 | c.857G>A p.G286E | Missense Mutation (SNP) | VAF 28/62 reads (45%) | SIFT tolerated (0.2); PolyPhen benign (0.347); catalogued as COSV100880667; called by muse, mutect2, varscan2
- CTAGE1 | c.464C>T p.S155L | Missense Mutation (SNP) | VAF 91/273 reads (33%) | SIFT tolerated (0.08); PolyPhen probably damaging (0.996); catalogued as rs776939884, COSV66944864; called by muse, mutect2, varscan2
- CTAGE15 | c.1235A>C p.E412A | Missense Mutation (SNP) | VAF 49/287 reads (17%) | SIFT deleterious (0.01); PolyPhen benign (0.003); catalogued as COSV101372135; called by muse, mutect2, varscan2
- CTC1 | c.568C>T p.P190S | Missense Mutation (SNP) | VAF 33/95 reads (35%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.92); catalogued as COSV59853480; called by muse, mutect2, varscan2
- CTCFL | c.1304C>T p.T435I | Missense Mutation (SNP) | VAF 154/369 reads (42%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.974); catalogued as COSV54774329; called by muse, mutect2, varscan2
- CTNNA2 | c.1684G>A p.E562K | Missense Mutation (SNP) | VAF 67/165 reads (41%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.494); catalogued as rs199781520, COSV100559758; called by muse, mutect2, varscan2
- CTNNA3 | c.544G>A p.E182K | Missense Mutation (SNP) | VAF 45/126 reads (36%) | SIFT tolerated (0.52); PolyPhen probably damaging (0.973); catalogued as COSV57721000; called by muse, mutect2, varscan2
- CUL3 | c.625T>A p.F209I | Missense Mutation (SNP) | VAF 22/85 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.981); catalogued as rs1418778821, COSV52361421; called by muse, mutect2, varscan2
- CUX2 | c.437-2A>C p.X146_splice | Splice Site (SNP) | VAF 5/13 reads (38%) | catalogued as COSV99919107; called by muse, mutect2, varscan2
- CWH43 | c.1048G>A p.D350N | Missense Mutation (SNP) | VAF 4/40 reads (10%) | SIFT tolerated (0.11); PolyPhen benign (0.229); catalogued as COSV99893087; called by muse, mutect2
- CXADR | c.941C>T p.S314F | Missense Mutation (SNP) | VAF 30/95 reads (32%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.878); catalogued as COSV99515060, COSV99515136; called by muse, mutect2, varscan2
- CXCR1 | c.904C>T p.P302S | Missense Mutation (SNP) | VAF 41/122 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1213480660, COSV55283094, COSV99826282; called by muse, mutect2, varscan2
- CXorf66 | c.931C>T p.R311C | Missense Mutation (SNP) | VAF 82/243 reads (34%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.496); catalogued as rs200754289, COSV65169523, COSV65169966; called by muse, mutect2, varscan2
- CYLC1 | c.431C>T p.S144F | Missense Mutation (SNP) | VAF 24/61 reads (39%) | SIFT tolerated (0.68); PolyPhen benign (0.018); catalogued as COSV100254317; called by muse, mutect2, varscan2
- CYLC2 | c.583G>A p.D195N | Missense Mutation (SNP) | VAF 44/60 reads (73%) | SIFT tolerated (0.65); PolyPhen benign (0.038); catalogued as COSV66336472; called by muse, mutect2, varscan2
- CYP11A1 | c.110G>A p.G37E | Missense Mutation (SNP) | VAF 37/81 reads (46%) | SIFT tolerated (0.15); PolyPhen possibly damaging (0.544); catalogued as rs750566795, COSV51433908; called by muse, mutect2, varscan2
- CYP19A1 | c.545C>T p.S182L | Missense Mutation (SNP) | VAF 38/86 reads (44%) | SIFT tolerated (0.4); PolyPhen benign (0.003); catalogued as rs1237240555, COSV53059215; called by muse, mutect2, varscan2
- CYP19A1 | c.302C>T p.S101L | Missense Mutation (SNP) | VAF 41/92 reads (45%) | SIFT deleterious (0); PolyPhen probably damaging (0.97); catalogued as COSV99547511; called by muse, mutect2, varscan2
- CYP1A2 | c.307G>A p.D103N | Missense Mutation (SNP) | VAF 33/76 reads (43%) | SIFT tolerated (0.07); PolyPhen benign (0.052); catalogued as rs763535401, COSV59659224; called by muse, mutect2, varscan2
- CYP27C1 | c.1100G>A p.R367Q | Missense Mutation (SNP) | VAF 36/88 reads (41%) | SIFT tolerated (1); PolyPhen benign (0.019); catalogued as rs1418713591, COSV58866324; called by muse, mutect2, varscan2
- CYP2C18 | c.236G>A p.G79E | Missense Mutation (SNP) | VAF 89/253 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.984); catalogued as COSV53670655, COSV53672567; called by muse, mutect2, varscan2
- CYP2F1 | c.83G>A p.G28E | Missense Mutation (SNP) | VAF 110/316 reads (35%) | SIFT tolerated (0.07); PolyPhen benign (0.19); catalogued as COSV58526711; called by muse, varscan2
- CYP2S1 | c.772A>C p.N258H | Missense Mutation (SNP) | VAF 32/90 reads (36%) | SIFT deleterious (0); PolyPhen benign (0.295); catalogued as COSV100027388; called by muse, mutect2, varscan2
- CYP4A22 | c.1358G>A p.G453E | Missense Mutation (SNP) | VAF 187/512 reads (37%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.993); catalogued as rs267598634, COSV99594736; called by muse, mutect2, varscan2
- CYP4F11 | c.1330C>T p.R444C | Missense Mutation (SNP) | VAF 80/190 reads (42%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.924); catalogued as rs146962563, COSV99930683; called by muse, mutect2, varscan2
- CYP4F2 | c.648G>A p.E216= | Splice Region (SNP) | VAF 62/165 reads (38%) | catalogued as COSV50000519; called by muse, mutect2, varscan2
- CYP4Z1 | c.1027G>A p.E343K | Missense Mutation (SNP) | VAF 30/71 reads (42%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1436665985, COSV61963983; called by muse, mutect2, varscan2
- CYP8B1 | c.964G>A p.E322K | Missense Mutation (SNP) | VAF 20/47 reads (43%) | SIFT tolerated (0.15); PolyPhen benign (0.151); catalogued as COSV60227339; called by muse, mutect2, varscan2
- CYTH1 | c.1181C>T p.S394F | Missense Mutation (SNP) | VAF 4/22 reads (18%) | SIFT deleterious (0.01); PolyPhen benign (0.287); catalogued as rs1256738831, COSV63119924; called by muse, mutect2
- DACH2 | c.397G>A p.G133R | Missense Mutation (SNP) | VAF 30/81 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs201644507, COSV100912838, COSV64161266; called by muse, mutect2, varscan2
- DAPP1 | c.611C>T p.P204L | Missense Mutation (SNP) | VAF 6/22 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs867913952, COSV99596729; called by muse, mutect2
- DBH | c.212C>T p.A71V | Missense Mutation (SNP) | VAF 44/54 reads (81%) | SIFT tolerated (0.57); PolyPhen benign (0.003); catalogued as rs1379708669, COSV99707974; called by muse, mutect2, varscan2
- DBR1 | c.589C>T p.R197* | Nonsense Mutation (SNP) | VAF 34/125 reads (27%) | catalogued as rs149610079; called by muse, mutect2, varscan2
- DCAF12L1 | c.320A>G p.N107S | Missense Mutation (SNP) | VAF 43/131 reads (33%) | SIFT tolerated (0.45); PolyPhen probably damaging (0.985); catalogued as COSV100948171; called by muse, mutect2, varscan2
- DCAF4L2 | c.1070C>T p.P357L | Missense Mutation (SNP) | VAF 34/56 reads (61%) | SIFT deleterious (0); PolyPhen possibly damaging (0.792); catalogued as COSV100150640, COSV100150926; called by muse, mutect2, varscan2
- DCAF4L2 | c.496G>A p.G166S | Missense Mutation (SNP) | VAF 56/75 reads (75%) | SIFT tolerated (0.49); PolyPhen benign (0.003); catalogued as COSV100150642; called by muse, mutect2, varscan2
- DCC | c.1502G>A p.R501Q | Missense Mutation (SNP) | VAF 30/64 reads (47%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.839); catalogued as rs776220441, COSV100498963; called by muse, mutect2, varscan2
- DCC | c.2065G>A p.G689R | Missense Mutation (SNP) | VAF 68/155 reads (44%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.995); catalogued as COSV100498966; called by muse, mutect2, varscan2
- DCC | c.3439G>A p.D1147N | Missense Mutation (SNP) | VAF 33/77 reads (43%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.999); catalogued as rs148589863; called by muse, mutect2, varscan2
- DCDC2 | c.377A>G p.N126S | Missense Mutation (SNP) | VAF 46/142 reads (32%) | SIFT tolerated (0.62); PolyPhen benign (0.217); catalogued as COSV101016120; called by muse, mutect2, varscan2
- DCN | c.439A>G p.K147E | Missense Mutation (SNP) | VAF 99/263 reads (38%) | SIFT deleterious (0.02); PolyPhen benign (0.001); catalogued as COSV99271949; called by muse, mutect2, varscan2
- DDR1 | c.1699C>T p.P567S (on ENST00000324771; = p.P530S on NM_001954.4) | Missense Mutation (SNP) | VAF 52/116 reads (45%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV100241244; called by muse, mutect2, varscan2
- DDR2 | c.2000C>T p.S667F | Missense Mutation (SNP) | VAF 68/170 reads (40%) | SIFT tolerated (0.07); PolyPhen benign (0.261); catalogued as rs1379193443, COSV63371051; called by muse, mutect2, varscan2
- DDX21 | c.1696C>T p.P566S | Missense Mutation (SNP) | VAF 19/62 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV100826493; called by muse, mutect2, varscan2
- DDX21 | c.1697C>T p.P566L | Missense Mutation (SNP) | VAF 20/64 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV100826495; called by muse, mutect2, varscan2
- DDX60 | c.1634C>T p.S545L | Missense Mutation (SNP) | VAF 42/67 reads (63%) | SIFT deleterious (0); PolyPhen possibly damaging (0.835); catalogued as COSV101190324; called by muse, mutect2, varscan2
- DEFB125 | c.250G>A p.D84N | Missense Mutation (SNP) | VAF 67/200 reads (34%) | SIFT tolerated (0.3); PolyPhen benign (0.006); catalogued as COSV66703180; called by muse, mutect2, varscan2
- DEFB127 | c.4G>A p.G2R | Missense Mutation (SNP) | VAF 48/119 reads (40%) | SIFT tolerated (0.67); PolyPhen benign (0); catalogued as rs1455079299, COSV101213797; called by muse, mutect2, varscan2
- DENND1C | c.2147C>T p.P716L | Missense Mutation (SNP) | VAF 13/24 reads (54%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.278); catalogued as rs1251021211, COSV100375233; called by muse, mutect2, varscan2
- DENND2A | c.184C>T p.P62S | Missense Mutation (SNP) | VAF 58/281 reads (21%) | SIFT tolerated (0.1); PolyPhen benign (0.003); catalogued as COSV99325781; called by muse, mutect2, varscan2
- DENR | c.458C>T p.S153F | Missense Mutation (SNP) | VAF 8/15 reads (53%) | SIFT deleterious (0); PolyPhen probably damaging (0.953); catalogued as COSV99757309; called by muse, mutect2, varscan2
- DEUP1 | c.157G>A p.E53K | Missense Mutation (SNP) | VAF 27/55 reads (49%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV53210045, COSV99976913; called by muse, mutect2, varscan2
- DGCR8 | c.694G>A p.E232K | Missense Mutation (SNP) | VAF 76/227 reads (33%) | SIFT deleterious (0.02); PolyPhen benign (0.358); catalogued as rs1484467022, COSV100707868; called by muse, mutect2, varscan2
- DHX36 | c.2197A>C p.I733L | Missense Mutation (SNP) | VAF 29/84 reads (35%) | SIFT tolerated (0.26); PolyPhen benign (0.066); catalogued as COSV100273442; called by muse, mutect2, varscan2
- DIP2B | c.608C>T p.S203F | Missense Mutation (SNP) | VAF 30/109 reads (28%) | SIFT deleterious (0.03); PolyPhen benign (0.058); catalogued as COSV99998181; called by muse, mutect2, varscan2
- DLG2 | c.494A>T p.K165I | Missense Mutation (SNP) | VAF 30/81 reads (37%) | SIFT tolerated (0.15); PolyPhen benign (0.243); catalogued as COSV99713780; called by muse, mutect2, varscan2
- DLG5 | c.5060C>T p.S1687F | Missense Mutation (SNP) | VAF 45/135 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV100967327, COSV64949168; called by muse, mutect2, varscan2
- DLGAP1 | c.975G>A p.W325* | Nonsense Mutation (SNP) | VAF 58/83 reads (70%) | catalogued as COSV100228960; called by muse, mutect2, varscan2
- DLK1 | c.991G>A p.E331K | Missense Mutation (SNP) | VAF 82/126 reads (65%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.986); catalogued as rs759953560, COSV57990651; called by muse, mutect2, varscan2
- DMC1 | c.385C>T p.R129C | Missense Mutation (SNP) | VAF 30/65 reads (46%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs201014421, COSV53258054; called by muse, mutect2, varscan2
- DMD | c.7015C>T p.H2339Y | Missense Mutation (SNP) | VAF 31/52 reads (60%) | SIFT deleterious (0.01); PolyPhen benign (0.001); catalogued as COSV100626469; called by muse, mutect2, varscan2
- DMD | c.2785G>A p.E929K | Missense Mutation (SNP) | VAF 19/45 reads (42%) | SIFT tolerated (0.13); PolyPhen benign (0.009); catalogued as rs772679497, COSV100818746; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- DMP1 | c.478G>A p.D160N | Missense Mutation (SNP) | VAF 30/36 reads (83%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.896); catalogued as COSV99218583; called by muse, mutect2, varscan2
- DMPK | c.415C>T p.Q139* | Nonsense Mutation (SNP) | VAF 71/188 reads (38%) | catalogued as COSV99352900; called by muse, mutect2, varscan2
- DNAAF1 | c.1537C>T p.P513S | Missense Mutation (SNP) | VAF 12/46 reads (26%) | SIFT tolerated (0.34); PolyPhen benign (0.046); catalogued as COSV100533729, COSV57577928; called by muse, mutect2, varscan2
- DNAH10 | c.1024G>A p.E342K (on ENST00000409039; = p.E281K on NM_207437.3) | Missense Mutation (SNP) | VAF 23/58 reads (40%) | SIFT deleterious (0.05); PolyPhen benign (0.09); catalogued as rs202143111, COSV101292111; called by muse, mutect2, varscan2
- DNAH11 | c.7468G>A p.A2490T | Missense Mutation (SNP) | VAF 8/28 reads (29%) | SIFT tolerated (0.9); PolyPhen benign (0); catalogued as COSV100178258; called by muse, mutect2, varscan2
- DNAH17 | c.5587G>A p.A1863T | Missense Mutation (SNP) | VAF 12/21 reads (57%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.986); catalogued as rs1424093381, COSV101101764; called by muse, mutect2, varscan2
- DNAH3 | c.11968C>T p.P3990S | Missense Mutation (SNP) | VAF 46/112 reads (41%) | SIFT deleterious (0.03); PolyPhen probably damaging (1); catalogued as COSV99765863; called by muse, varscan2
- DNAH3 | c.3967C>T p.Q1323* | Nonsense Mutation (SNP) | VAF 30/74 reads (41%) | catalogued as rs976007808, COSV54549914; called by muse, mutect2, varscan2
- DNAH3 | c.3422G>A p.R1141Q | Missense Mutation (SNP) | VAF 62/138 reads (45%) | SIFT tolerated (0.2); PolyPhen benign (0.019); catalogued as rs941289345, COSV99765878; called by muse, mutect2, varscan2
- DNAH3 | c.913G>A p.E305K | Missense Mutation (SNP) | VAF 55/123 reads (45%) | SIFT tolerated (0.08); PolyPhen probably damaging (0.994); catalogued as rs866290636, COSV54531212; called by muse, mutect2, varscan2
- DNAH5 | c.13816G>A p.A4606T | Missense Mutation (SNP) | VAF 38/88 reads (43%) | SIFT tolerated (0.59); PolyPhen benign (0.005); catalogued as COSV99447004; called by muse, mutect2, varscan2
- DNAH5 | c.11888C>T p.S3963L | Missense Mutation (SNP) | VAF 32/85 reads (38%) | SIFT tolerated (0.09); PolyPhen benign (0.059); catalogued as rs191057833, COSV54214570, COSV99445303; called by muse, mutect2, varscan2
- DNAH5 | c.10667C>T p.P3556L | Missense Mutation (SNP) | VAF 86/226 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as rs1179894393, COSV54205876; called by muse, mutect2, varscan2
- DNAH5 | c.6253C>T p.P2085S | Missense Mutation (SNP) | VAF 27/72 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV54251521; called by muse, mutect2, varscan2
- DNAH5 | c.2084C>T p.S695L | Missense Mutation (SNP) | VAF 27/69 reads (39%) | SIFT deleterious (0.04); PolyPhen benign (0.405); catalogued as COSV99447025; called by muse, mutect2, varscan2
- DNAH7 | c.10116G>A p.W3372* | Nonsense Mutation (SNP) | VAF 23/77 reads (30%) | catalogued as rs1393406980, COSV100414475; called by muse, mutect2, varscan2
- DNAH7 | c.10115G>A p.W3372* | Nonsense Mutation (SNP) | VAF 22/76 reads (29%) | catalogued as COSV100414476, COSV56789206; called by muse, mutect2, varscan2
- DNAH7 | c.6425C>T p.P2142L | Missense Mutation (SNP) | VAF 42/80 reads (53%) | SIFT tolerated (0.06); PolyPhen benign (0.309); catalogued as rs746313793, COSV100414477; called by muse, mutect2, varscan2
- DNAH7 | c.2402G>A p.G801E | Missense Mutation (SNP) | VAF 71/202 reads (35%) | SIFT tolerated (0.22); PolyPhen probably damaging (0.988); catalogued as rs763905290, COSV56790927; called by muse, mutect2, varscan2
- DNAH8 | c.1712C>T p.A571V | Missense Mutation (SNP) | VAF 28/71 reads (39%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.869); catalogued as COSV100544034; called by muse, mutect2, varscan2
- DNAH8 | c.6652G>A p.V2218I | Missense Mutation (SNP) | VAF 36/102 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as rs749048233, COSV59438407; called by muse, mutect2, varscan2
- DNAH8 | c.7716G>A p.M2572I | Missense Mutation (SNP) | VAF 38/94 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1321513367, COSV59448576; called by muse, mutect2, varscan2
- DNAH8 | c.10520C>T p.S3507F | Missense Mutation (SNP) | VAF 94/222 reads (42%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV59429318; called by muse, mutect2, varscan2
- DNAH8 | c.11166-1G>A p.X3722_splice | Splice Site (SNP) | VAF 23/67 reads (34%) | catalogued as rs1230535170, COSV100544036, COSV100547060; called by muse, mutect2, varscan2
- DNAH9 | c.949C>T p.Q317* | Nonsense Mutation (SNP) | VAF 18/52 reads (35%) | catalogued as COSV99304955; called by muse, mutect2, varscan2
- DNAJC10 | c.622C>T p.R208W | Missense Mutation (SNP) | VAF 24/83 reads (29%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.847); catalogued as rs372451587, COSV51135757; called by muse, mutect2, varscan2
- DNAJC5B | c.64G>A p.E22K | Missense Mutation (SNP) | VAF 52/112 reads (46%) | SIFT tolerated (0.51); PolyPhen benign (0.041); catalogued as rs141686243, COSV52535470; called by muse, mutect2, varscan2
- DNASE1L3 | c.109G>A p.E37K | Missense Mutation (SNP) | VAF 97/263 reads (37%) | SIFT tolerated (0.79); PolyPhen benign (0.096); catalogued as COSV100568634; called by muse, mutect2, varscan2
- DOCK1 | c.5445G>A p.M1815I | Missense Mutation (SNP) | VAF 18/30 reads (60%) | SIFT tolerated (0.53); PolyPhen benign (0); catalogued as COSV99728043; called by muse, mutect2, varscan2
- DOCK11 | c.1879C>T p.P627S | Missense Mutation (SNP) | VAF 42/113 reads (37%) | SIFT tolerated (0.31); PolyPhen probably damaging (0.985); catalogued as COSV99353299; called by muse, mutect2
- DOCK11 | c.5137G>A p.E1713K | Missense Mutation (SNP) | VAF 56/147 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.955); catalogued as COSV52236748, COSV99353301; called by muse, mutect2, varscan2
- DOCK2 | c.1506G>A p.M502I | Missense Mutation (SNP) | VAF 43/124 reads (35%) | SIFT tolerated (0.15); PolyPhen probably damaging (0.977); catalogued as rs1228625365, COSV56950054, COSV99911122; called by muse, mutect2, varscan2
- DOCK3 | c.6070G>A p.E2024K | Missense Mutation (SNP) | VAF 8/20 reads (40%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.142); catalogued as rs782129881, COSV99810282; called by muse, mutect2, varscan2
- DOCK5 | c.1765C>A p.P589T | Missense Mutation (SNP) | VAF 29/94 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as COSV99376463; called by muse, mutect2, varscan2
- DOCK5 | c.1766C>T p.P589L | Missense Mutation (SNP) | VAF 29/95 reads (31%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.998); catalogued as COSV99376465; called by muse, mutect2, varscan2
- DOCK6 | c.3674C>T p.P1225L | Missense Mutation (SNP) | VAF 15/41 reads (37%) | SIFT tolerated (0.53); PolyPhen benign (0.063); catalogued as rs1467040961, COSV99625105; called by muse, mutect2, varscan2
- DOLPP1 | c.341C>T p.S114F | Missense Mutation (SNP) | VAF 62/140 reads (44%) | SIFT tolerated (0.13); PolyPhen benign (0.003); catalogued as rs867823744, COSV59910069; called by muse, mutect2, varscan2
- DOP1A | c.1745C>T p.P582L | Missense Mutation (SNP) | VAF 32/94 reads (34%) | SIFT tolerated (0.06); PolyPhen benign (0.005); catalogued as rs781564736, COSV99381342; called by muse, mutect2, varscan2
- DOP1B | c.4094C>T p.S1365F | Missense Mutation (SNP) | VAF 44/121 reads (36%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.45); catalogued as COSV101215184; called by muse, mutect2, varscan2
- DOT1L | c.3623C>T p.S1208F | Missense Mutation (SNP) | VAF 87/190 reads (46%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.952); catalogued as COSV67108876; called by muse, mutect2, varscan2
- DPP10 | c.514C>T p.P172S | Missense Mutation (SNP) | VAF 19/62 reads (31%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.996); catalogued as COSV59722322; called by muse, mutect2, varscan2
- DPP6 | c.2386C>T p.H796Y (on ENST00000377770 / NM_001364500.2; = p.H734Y on NM_001936.5) | Missense Mutation (SNP) | VAF 5/20 reads (25%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as rs758767496, COSV59620823; called by muse, mutect2
- DPP9 | c.2506C>A p.P836T (on ENST00000598800; = p.P865T on NM_139159.5) | Missense Mutation (SNP) | VAF 4/17 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV99505847; called by muse, mutect2
- DPPA2 | c.113A>T p.E38V | Missense Mutation (SNP) | VAF 90/222 reads (41%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.676); catalogued as COSV101524749; called by muse, mutect2, varscan2
- DPRX | c.290C>T p.T97I | Missense Mutation (SNP) | VAF 47/128 reads (37%) | SIFT tolerated (0.07); PolyPhen benign (0.013); catalogued as COSV64949706; called by muse, mutect2, varscan2
- DPYD | c.353C>T p.S118F | Missense Mutation (SNP) | VAF 46/127 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100031395, COSV100031760; called by muse, mutect2, varscan2
- DRD3 | c.733C>T p.P245S | Missense Mutation (SNP) | VAF 47/130 reads (36%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.575); catalogued as rs1174905497, COSV99879273; called by muse, mutect2, varscan2
- DRP2 | c.1655G>A p.G552E | Missense Mutation (SNP) | VAF 46/123 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100871847; called by muse, mutect2, varscan2
- DRP2 | c.2453G>A p.S818N | Missense Mutation (SNP) | VAF 7/18 reads (39%) | SIFT tolerated (0.22); PolyPhen benign (0.001); catalogued as rs1478819725, COSV101235167; called by muse, mutect2, varscan2
- DSC3 | c.2563G>A p.E855K | Missense Mutation (SNP) | VAF 43/93 reads (46%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV100844561; called by muse, mutect2, varscan2
- DSC3 | c.2372C>T p.S791F | Missense Mutation (SNP) | VAF 28/77 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (0.935); catalogued as rs267605140, COSV64572327; called by muse, mutect2, varscan2
- DSCAM | c.5721G>A p.M1907I | Missense Mutation (SNP) | VAF 27/78 reads (35%) | SIFT tolerated, low confidence (0.12); PolyPhen possibly damaging (0.838); catalogued as COSV68029944; called by muse, mutect2, varscan2
- DSCAM | c.2714G>A p.W905* | Nonsense Mutation (SNP) | VAF 22/64 reads (34%) | catalogued as COSV101259582; called by muse, mutect2, varscan2
- DSCAM | c.202G>A p.D68N | Missense Mutation (SNP) | VAF 44/100 reads (44%) | SIFT tolerated (0.18); PolyPhen benign (0.015); catalogued as rs367690354, COSV68648441; called by muse, mutect2, varscan2
- DSEL | c.3430C>T p.P1144S | Missense Mutation (SNP) | VAF 26/91 reads (29%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.547); catalogued as rs749689370, COSV100025405, COSV59490446; called by muse, mutect2, varscan2
- DSG2 | c.1150G>A p.E384K | Missense Mutation (SNP) | VAF 63/168 reads (38%) | SIFT deleterious (0); PolyPhen possibly damaging (0.784); catalogued as COSV99852962; called by muse, mutect2, varscan2
- DSG3 | c.2009G>A p.G670E | Missense Mutation (SNP) | VAF 36/79 reads (46%) | SIFT deleterious (0.05); PolyPhen benign (0.434); catalogued as rs1243605673, COSV57128501, COSV99934489; called by muse, mutect2, varscan2
- DSG4 | c.1556C>T p.S519F | Missense Mutation (SNP) | VAF 27/86 reads (31%) | SIFT deleterious (0.04); PolyPhen benign (0.401); catalogued as COSV100355598; called by muse, mutect2, varscan2
- DST | c.21100C>T p.P7034S (on ENST00000361203 / NM_001374722.1; = p.P4731S on NM_015548.5) | Missense Mutation (SNP) | VAF 38/85 reads (45%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs376692141; called by muse, mutect2, varscan2
- DSTYK | c.2443C>T p.H815Y | Missense Mutation (SNP) | VAF 59/138 reads (43%) | SIFT deleterious (0); PolyPhen possibly damaging (0.866); catalogued as rs868788895, COSV65688701; called by muse, mutect2, varscan2
- DUOX1 | c.304T>G p.F102V | Missense Mutation (SNP) | VAF 30/71 reads (42%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99972972; called by muse, mutect2, varscan2
- DUOX1 | c.1824G>A p.V608= | Splice Region (SNP) | VAF 12/35 reads (34%) | catalogued as COSV100367758; called by muse, mutect2, varscan2
- DUS3L | c.1807C>T p.P603S | Missense Mutation (SNP) | VAF 6/13 reads (46%) | SIFT deleterious (0); PolyPhen possibly damaging (0.624); catalogued as rs758312337, COSV57832246; called by muse, varscan2
- DYNLRB2 | c.25A>G p.K9E | Missense Mutation (SNP) | VAF 57/119 reads (48%) | SIFT tolerated (0.07); PolyPhen benign (0.443); catalogued as COSV100009683; called by muse, mutect2, varscan2
- DYRK1B | c.1583C>T p.A528V | Missense Mutation (SNP) | VAF 23/65 reads (35%) | SIFT tolerated, low confidence (0.11); PolyPhen benign (0.003); catalogued as rs1396611956, COSV100546493; called by muse, mutect2, varscan2
- DYRK3 | c.1024C>A p.L342I | Missense Mutation (SNP) | VAF 54/149 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); catalogued as COSV100895643; called by muse, mutect2, varscan2
- DYSF | c.1061G>A p.R354K | Missense Mutation (SNP) | VAF 73/204 reads (36%) | SIFT tolerated (1); PolyPhen benign (0.003); catalogued as COSV99245484; called by muse, mutect2, varscan2
- DYTN | c.1237G>A p.D413N | Missense Mutation (SNP) | VAF 25/89 reads (28%) | SIFT tolerated (0.16); PolyPhen benign (0.003); catalogued as COSV101510814; called by muse, mutect2, varscan2
- DZANK1 | c.319C>T p.P107S | Missense Mutation (SNP) | VAF 13/30 reads (43%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.571); catalogued as rs1348493361, COSV99362098; called by muse, mutect2
- DZIP1 | c.1742G>A p.R581K (on ENST00000347108; = p.R562K on NM_014934.5) | Missense Mutation (SNP) | VAF 140/182 reads (77%) | SIFT deleterious (0.03); PolyPhen benign (0.051); catalogued as COSV100714038; called by muse, mutect2, varscan2
- DZIP1 | c.1741A>T p.R581* (on ENST00000347108; = p.R562* on NM_014934.5) | Nonsense Mutation (SNP) | VAF 145/188 reads (77%) | catalogued as COSV100714040; called by muse, mutect2, varscan2
- DZIP1 | c.1075G>A p.D359N | Missense Mutation (SNP) | VAF 12/156 reads (8%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.996); catalogued as rs1016275069, COSV61265858; called by muse, mutect2
- E2F6 | c.125T>A p.I42N | Missense Mutation (SNP) | VAF 20/65 reads (31%) | SIFT tolerated (0.17); PolyPhen possibly damaging (0.753); catalogued as COSV100215279; called by muse, mutect2, varscan2
- EBF2 | c.1688G>A p.G563E | Missense Mutation (SNP) | VAF 44/132 reads (33%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.197); catalogued as rs776859966, COSV68776429; called by muse, mutect2, varscan2
- EBF2 | c.1490G>A p.G497E | Missense Mutation (SNP) | VAF 22/70 reads (31%) | SIFT deleterious, low confidence (0.04); PolyPhen benign (0.023); catalogued as rs267601872, COSV101282122, COSV101282144; called by muse, mutect2, varscan2
- EBF2 | c.880G>A p.E294K | Missense Mutation (SNP) | VAF 38/92 reads (41%) | SIFT deleterious (0.04); PolyPhen benign (0.286); catalogued as rs199818972, COSV68778709; called by muse, mutect2, varscan2
- ECRG4 | c.280G>A p.E94K | Missense Mutation (SNP) | VAF 30/90 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as rs1298098125, COSV52999902; called by muse, mutect2, varscan2
- EDA2R | c.559G>A p.E187K | Missense Mutation (SNP) | VAF 10/31 reads (32%) | SIFT tolerated (0.15); PolyPhen benign (0.025); catalogued as rs1046582103, COSV99490569; called by muse, mutect2, varscan2
- EDA2R | c.88G>A p.D30N | Missense Mutation (SNP) | VAF 10/26 reads (38%) | SIFT deleterious (0); PolyPhen possibly damaging (0.89); catalogued as COSV99037181, COSV99490574; called by muse, mutect2, varscan2
- EDAR | c.236T>A p.F79Y | Missense Mutation (SNP) | VAF 34/88 reads (39%) | SIFT tolerated (0.36); PolyPhen benign (0.006); catalogued as COSV99303270; called by muse, mutect2, varscan2
- EDEM3 | c.1348C>T p.R450C | Missense Mutation (SNP) | VAF 54/150 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs771252507, COSV58926021, COSV58926423; called by muse, mutect2, varscan2
- EDIL3 | c.1304G>A p.G435E | Missense Mutation (SNP) | VAF 48/118 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV56896466; called by muse, varscan2
- EDNRA | c.790T>G p.F264V | Missense Mutation (SNP) | VAF 111/283 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); catalogued as COSV100163290; called by muse, mutect2, varscan2
- EDRF1 | c.785C>T p.S262F | Missense Mutation (SNP) | VAF 22/65 reads (34%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.742); catalogued as COSV100523342; called by muse, mutect2, varscan2
- EEF1AKMT2 | c.397A>G p.K133E | Missense Mutation (SNP) | VAF 10/34 reads (29%) | SIFT tolerated (0.47); PolyPhen possibly damaging (0.519); catalogued as rs1442532784, COSV100918922; called by muse, mutect2
- EEF2K | c.679C>T p.H227Y | Missense Mutation (SNP) | VAF 33/75 reads (44%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as rs770832437, COSV99532800; called by muse, mutect2, varscan2
- EFCAB3 | c.1274G>A p.G425E | Missense Mutation (SNP) | VAF 64/182 reads (35%) | SIFT tolerated, low confidence (0.08); PolyPhen benign (0.019); catalogued as COSV100540098; called by muse, mutect2, varscan2
- EFCAB7 | c.731C>T p.S244F | Missense Mutation (SNP) | VAF 74/110 reads (67%) | SIFT deleterious (0); PolyPhen probably damaging (0.921); catalogued as COSV100937618; called by muse, mutect2, varscan2
- EHHADH | c.851C>T p.P284L | Missense Mutation (SNP) | VAF 45/113 reads (40%) | SIFT tolerated (0.09); PolyPhen probably damaging (0.934); catalogued as rs1425914283, COSV51628230; called by muse, mutect2, varscan2
- EIF2AK4 | c.4305C>T p.S1435= | Splice Region (SNP) | VAF 27/78 reads (35%) | catalogued as COSV99774343; called by muse, mutect2, varscan2
- EIF3A | c.1762C>T p.Q588* | Nonsense Mutation (SNP) | VAF 23/59 reads (39%) | catalogued as COSV100974547; called by muse, mutect2, varscan2
- EIF4G3 | c.4042C>T p.P1348S | Missense Mutation (SNP) | VAF 28/89 reads (31%) | SIFT tolerated (0.06); PolyPhen benign (0.235); catalogued as COSV51675642; called by muse, mutect2, varscan2
- ELAC2 | c.2197C>T p.P733S | Missense Mutation (SNP) | VAF 43/106 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs758585863, COSV99310365; called by muse, mutect2, varscan2
- ELAPOR1 | c.965C>T p.S322F | Missense Mutation (SNP) | VAF 64/179 reads (36%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.875); catalogued as rs1432887633, COSV100884418; called by muse, mutect2, varscan2
- ELAPOR2 | c.1913C>T p.P638L (on ENST00000450689 / NM_001142749.3; = p.P471L on NM_152748.4 and 2 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 34/79 reads (43%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.525); catalogued as COSV99788458; called by muse, mutect2, varscan2
- ELF3 | c.325G>A p.E109K | Missense Mutation (SNP) | VAF 39/68 reads (57%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.589); catalogued as COSV62838043; called by muse, mutect2, varscan2
- ELMO1 | c.106G>A p.E36K | Missense Mutation (SNP) | VAF 145/408 reads (36%) | SIFT tolerated (0.06); PolyPhen benign (0.074); catalogued as COSV60302824; called by muse, mutect2, varscan2
- ELOA2 | c.2002G>A p.E668K | Missense Mutation (SNP) | VAF 109/236 reads (46%) | SIFT deleterious (0.01); PolyPhen benign (0.033); catalogued as rs1455365305, COSV55298376; called by muse, mutect2, varscan2
- ELOA2 | c.1747G>A p.E583K | Missense Mutation (SNP) | VAF 31/86 reads (36%) | SIFT deleterious (0.05); PolyPhen benign (0.161); catalogued as rs769385321, COSV55294609; called by muse, mutect2, varscan2
- ELOVL2 | c.448C>T p.H150Y | Missense Mutation (SNP) | VAF 47/135 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100675823, COSV61154991; called by muse, mutect2, varscan2
- EMC1 | c.2003C>T p.S668F | Missense Mutation (SNP) | VAF 68/151 reads (45%) | SIFT deleterious (0); PolyPhen possibly damaging (0.819); catalogued as COSV100916428; called by muse, mutect2, varscan2
- ENC1 | c.1210C>T p.P404S | Missense Mutation (SNP) | VAF 42/116 reads (36%) | SIFT deleterious, low confidence (0.03); PolyPhen probably damaging (0.973); catalogued as COSV100187973; called by muse, mutect2, varscan2
- ENOX1 | c.1745C>T p.P582L | Missense Mutation (SNP) | VAF 21/40 reads (53%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV54899567; called by muse, mutect2, varscan2
- ENOX2 | c.784G>A p.D262N (on ENST00000338144 / NM_001382520.1; = p.D233N on NM_006375.3 and 2 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 34/96 reads (35%) | SIFT tolerated (0.1); PolyPhen possibly damaging (0.893); catalogued as COSV100583947, COSV57651197; called by muse, mutect2, varscan2
- ENPEP | c.911G>A p.G304E | Missense Mutation (SNP) | VAF 36/61 reads (59%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as rs756936512, COSV54449513; called by muse, mutect2, varscan2
- EP300 | c.2779C>T p.P927S | Missense Mutation (SNP) | VAF 11/32 reads (34%) | SIFT tolerated (0.12); PolyPhen benign (0.098); catalogued as rs1274868610, COSV99607909; called by muse, mutect2, varscan2
- EP400 | c.5402C>T p.P1801L | Missense Mutation (SNP) | VAF 41/97 reads (42%) | SIFT deleterious (0); PolyPhen benign (0.358); catalogued as rs545633950, COSV57786154; called by muse, mutect2, varscan2
- EPHA4 | c.2164C>T p.Q722* | Nonsense Mutation (SNP) | VAF 61/147 reads (41%) | catalogued as COSV99916054; called by muse, mutect2, varscan2
- EPHA6 | c.1564C>T p.P522S | Missense Mutation (SNP) | VAF 48/134 reads (36%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.611); catalogued as COSV101060623, COSV67562008; called by muse, mutect2, varscan2
- EPHB1 | c.1202C>T p.P401L | Missense Mutation (SNP) | VAF 28/74 reads (38%) | SIFT tolerated (0.14); PolyPhen benign (0.003); catalogued as rs541095826, COSV101212876; called by muse, mutect2, varscan2
- EPPK1 | c.5104G>A p.D1702N | Missense Mutation (SNP) | VAF 54/86 reads (63%) | SIFT deleterious (0); PolyPhen benign (0.088); catalogued as COSV101599782; called by muse, mutect2, varscan2
- EPPK1 | c.3219G>A p.M1073I | Missense Mutation (SNP) | VAF 13/18 reads (72%) | SIFT tolerated (0.11); PolyPhen benign (0.045); catalogued as rs782418603, COSV101599783; called by muse, mutect2
- EPS15L1 | c.1906C>T p.P636S | Missense Mutation (SNP) | VAF 65/172 reads (38%) | SIFT deleterious (0); PolyPhen benign (0.02); catalogued as rs750191435, COSV99932850; called by muse, mutect2, varscan2
- EPSTI1 | c.335G>A p.G112E | Missense Mutation (SNP) | VAF 16/33 reads (48%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs890594443; called by muse, mutect2, varscan2
- ERCC4 | c.1597G>A p.E533K | Missense Mutation (SNP) | VAF 44/99 reads (44%) | SIFT tolerated (0.4); PolyPhen benign (0.022); catalogued as COSV100318761; called by muse, mutect2, varscan2
- ERCC6 | c.2120T>C p.F707S | Missense Mutation (SNP) | VAF 26/77 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as COSV100875810; called by muse, mutect2, varscan2
- ERI3 | c.392C>T p.S131F | Missense Mutation (SNP) | VAF 123/313 reads (39%) | SIFT deleterious (0.02); PolyPhen benign (0.011); catalogued as COSV100952078; called by muse, mutect2, varscan2
- ERN1 | c.2274T>A p.F758L | Missense Mutation (SNP) | VAF 17/49 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV101458414; called by muse, mutect2, varscan2
- ERN1 | c.1043G>A p.S348N | Missense Mutation (SNP) | VAF 22/64 reads (34%) | SIFT tolerated (0.14); PolyPhen benign (0.006); catalogued as COSV101458415; called by muse, mutect2, varscan2
- ESM1 | c.547C>T p.P183S | Missense Mutation (SNP) | VAF 52/125 reads (42%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as rs1260213119, COSV101195624; called by muse, mutect2, varscan2
- ESRP1 | c.1064G>A p.G355E | Missense Mutation (SNP) | VAF 51/80 reads (64%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.927); catalogued as COSV100619244, COSV64409591; called by muse, mutect2, varscan2
- ESRRG | c.1000G>A p.E334K | Missense Mutation (SNP) | VAF 47/116 reads (41%) | SIFT tolerated (0.06); PolyPhen benign (0.007); catalogued as rs267598381, COSV63152230; called by muse, mutect2, varscan2
- ETV7 | c.620C>T p.S207F | Missense Mutation (SNP) | VAF 5/17 reads (29%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.62); catalogued as rs267601000, COSV100339122; called by muse, mutect2, varscan2
- EXOC3L1 | c.1287C>T p.I429= | Splice Region (SNP) | VAF 55/129 reads (43%) | catalogued as COSV99333520; called by muse, mutect2, varscan2
- EZHIP | c.1313C>T p.S438F | Missense Mutation (SNP) | VAF 37/93 reads (40%) | SIFT tolerated (0.25); PolyPhen benign (0.077); catalogued as COSV100539576; called by muse, mutect2, varscan2
- F8 | c.6404G>A p.R2135Q | Missense Mutation (SNP) | VAF 90/300 reads (30%) | SIFT deleterious (0.03); PolyPhen benign (0.395); catalogued as rs137852366, CM870007, COSV64273758; called by muse, mutect2, varscan2
- F8A1 | c.943C>T p.P315S | Missense Mutation (SNP) | VAF 11/40 reads (28%) | SIFT tolerated (0.55); PolyPhen benign (0.187); catalogued as COSV100371548; called by mutect2, varscan2
- FAAH2 | c.1563A>T p.K521N | Missense Mutation (SNP) | VAF 56/116 reads (48%) | SIFT tolerated (0.07); PolyPhen benign (0.105); catalogued as COSV100887209; called by muse, mutect2, varscan2
- FAAP100 | c.1652C>T p.S551F | Missense Mutation (SNP) | VAF 30/101 reads (30%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.875); catalogued as rs770609192, COSV100585278; called by muse, mutect2, varscan2
- FAF2 | c.315T>G p.F105L | Missense Mutation (SNP) | VAF 66/158 reads (42%) | SIFT tolerated (0.16); PolyPhen benign (0.01); catalogued as COSV99990340; called by muse, mutect2, varscan2
- FAHD2A | c.841C>T p.P281S | Missense Mutation (SNP) | VAF 21/53 reads (40%) | SIFT tolerated (0.14); PolyPhen benign (0.124); catalogued as COSV99271927; called by muse, mutect2, varscan2
- FAM117A | c.1174C>T p.P392S | Missense Mutation (SNP) | VAF 27/65 reads (42%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.992); catalogued as rs1011442776, COSV99539405; called by muse, mutect2, varscan2
- FAM120C | c.2830G>A p.G944R | Missense Mutation (SNP) | VAF 17/51 reads (33%) | SIFT deleterious (0); PolyPhen benign (0.323); catalogued as rs1557121880, COSV100069780; called by muse, mutect2, varscan2
- FAM135A | c.3133T>G p.S1045A (on ENST00000370479 / NM_001351599.1; = p.S832A on NM_020819.4 and 2 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 27/79 reads (34%) | SIFT tolerated (0.13); PolyPhen benign (0.003); catalogued as COSV99525504; called by muse, mutect2, varscan2
- FAM135B | c.3850G>A p.D1284N | Missense Mutation (SNP) | VAF 47/65 reads (72%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV52726361; called by muse, mutect2, varscan2
- FAM155A | c.590G>A p.R197Q | Missense Mutation (SNP) | VAF 20/188 reads (11%) | SIFT tolerated (0.13); PolyPhen benign (0.003); catalogued as rs757208205, COSV65565998, COSV65579689; called by muse, mutect2, varscan2
- FAM163A | c.337G>A p.V113M | Missense Mutation (SNP) | VAF 30/91 reads (33%) | SIFT tolerated (0.24); PolyPhen benign (0.019); catalogued as COSV100522968; called by muse, varscan2
- FAM166A | c.529C>T p.H177Y | Missense Mutation (SNP) | VAF 54/63 reads (86%) | SIFT tolerated (0.17); PolyPhen possibly damaging (0.829); catalogued as COSV100457778; called by muse, mutect2, varscan2
- FAM209B | c.17C>T p.S6L | Missense Mutation (SNP) | VAF 65/178 reads (37%) | SIFT tolerated (0.32); PolyPhen benign (0.011); catalogued as rs140276541, COSV100990998, COSV64915329; called by muse, mutect2, varscan2
- FAM3B | c.475G>A p.G159R | Missense Mutation (SNP) | VAF 56/163 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as rs768234423, COSV100783724; called by muse, mutect2, varscan2
- FAM71B | c.818G>A p.G273E | Missense Mutation (SNP) | VAF 77/185 reads (42%) | SIFT tolerated (0.37); PolyPhen benign (0.184); catalogued as rs771658846, COSV100261957, COSV57229138; called by muse, mutect2, varscan2
- FAM78A | c.490C>T p.P164S | Missense Mutation (SNP) | VAF 79/105 reads (75%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.996); catalogued as COSV55993293; called by muse, mutect2, varscan2
- FAM83B | c.674G>A p.G225E | Missense Mutation (SNP) | VAF 54/134 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100175022, COSV60922212; called by muse, mutect2, varscan2
- FAM83B | c.2635G>A p.E879K | Missense Mutation (SNP) | VAF 17/67 reads (25%) | SIFT tolerated (0.05); PolyPhen benign (0.172); catalogued as COSV100174229; called by muse, mutect2, varscan2
- FAM98B | c.974T>G p.F325C | Missense Mutation (SNP) | VAF 33/88 reads (38%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.339); catalogued as COSV101131454; called by muse, mutect2, varscan2
- FANCD2 | c.1355C>T p.S452L | Missense Mutation (SNP) | VAF 26/163 reads (16%) | SIFT tolerated (0.74); PolyPhen benign (0.014); catalogued as rs1231761206, COSV55033207; called by muse, varscan2
- FASLG | c.299G>A p.G100E | Missense Mutation (SNP) | VAF 14/62 reads (23%) | SIFT tolerated (0.05); PolyPhen benign (0.003); catalogued as COSV100390401; called by muse, mutect2, varscan2
- FASLG | c.766C>T p.H256Y | Missense Mutation (SNP) | VAF 84/217 reads (39%) | SIFT deleterious (0.04); PolyPhen benign (0.284); catalogued as COSV60680391; called by muse, mutect2, varscan2
- FAT1 | c.12170C>T p.S4057F | Missense Mutation (SNP) | VAF 29/39 reads (74%) | SIFT tolerated (0.75); PolyPhen possibly damaging (0.553); catalogued as COSV101499176; called by muse, mutect2, varscan2
- FAT1 | c.12169T>C p.S4057P | Missense Mutation (SNP) | VAF 29/39 reads (74%) | SIFT tolerated (0.31); PolyPhen benign (0.265); catalogued as COSV101499177; called by muse, mutect2, varscan2
- FAT3 | c.5938C>T p.L1980F | Missense Mutation (SNP) | VAF 135/170 reads (79%) | SIFT deleterious (0.02); PolyPhen benign (0.141); catalogued as COSV99963721; called by muse, mutect2, varscan2
- FAT4 | c.7546C>T p.H2516Y | Missense Mutation (SNP) | VAF 52/79 reads (66%) | SIFT tolerated (0.09); PolyPhen benign (0.396); catalogued as rs764574932, COSV58671662; called by muse, mutect2, varscan2
- FAT4 | c.8512G>A p.E2838K | Missense Mutation (SNP) | VAF 62/93 reads (67%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as rs1344481316, COSV100627843, COSV58693477; called by muse, mutect2, varscan2
- FBN2 | c.5138G>A p.G1713E | Missense Mutation (SNP) | VAF 59/153 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (0.96); catalogued as COSV52508217; called by muse, mutect2, varscan2
- FBN3 | c.5855T>A p.F1952Y | Missense Mutation (SNP) | VAF 14/40 reads (35%) | SIFT tolerated (0.25); PolyPhen benign (0.228); catalogued as COSV99560351; called by muse, mutect2
- FBXO15 | c.393T>A p.F131L | Missense Mutation (SNP) | VAF 27/73 reads (37%) | SIFT tolerated (0.34); PolyPhen benign (0); catalogued as COSV99503181; called by muse, mutect2, varscan2
- FBXO24 | c.1484G>A p.R495K (on ENST00000241071 / NM_033506.3; = p.R533K on NM_012172.5) | Missense Mutation (SNP) | VAF 23/74 reads (31%) | SIFT tolerated, low confidence (0.34); PolyPhen benign (0); catalogued as COSV99575126; called by muse, mutect2, varscan2
- FBXO28 | c.611C>T p.S204F | Missense Mutation (SNP) | VAF 53/159 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.986); catalogued as COSV100837391; called by muse, mutect2, varscan2
- FBXO34 | c.1358C>T p.S453F | Missense Mutation (SNP) | VAF 79/109 reads (72%) | SIFT deleterious (0.01); PolyPhen benign (0.38); catalogued as COSV100571880, COSV100571944; called by muse, mutect2, varscan2
- FBXO41 | c.2356G>A p.A786T | Missense Mutation (SNP) | VAF 10/24 reads (42%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as rs1174100560, COSV99721054; called by muse, mutect2, varscan2
- FBXO47 | c.176T>C p.L59S | Missense Mutation (SNP) | VAF 28/75 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (0.974); catalogued as COSV100960613; called by muse, mutect2, varscan2
- FCGR1A | c.1105G>A p.E369K | Missense Mutation (SNP) | VAF 26/81 reads (32%) | SIFT tolerated, low confidence (0.94); PolyPhen benign (0); catalogued as rs1553751918, COSV100977275; called by muse, mutect2, varscan2
- FCRL1 | c.380G>A p.G127E | Missense Mutation (SNP) | VAF 14/30 reads (47%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1472590784, COSV63823919, COSV63826159; called by muse, mutect2, varscan2
- FCRL3 | c.1932G>A p.M644I | Missense Mutation (SNP) | VAF 22/56 reads (39%) | SIFT tolerated (0.24); PolyPhen benign (0); catalogued as rs1487351748, COSV100943595, COSV63839173; called by muse, mutect2, varscan2
- FCRL4 | c.1534G>A p.D512N | Missense Mutation (SNP) | VAF 22/66 reads (33%) | SIFT deleterious (0.01); PolyPhen benign (0.375); catalogued as rs769507733, COSV54866855; called by muse, mutect2, varscan2
- FCRL5 | c.1702C>T p.L568F | Missense Mutation (SNP) | VAF 39/112 reads (35%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.838); catalogued as COSV100708708; called by muse, mutect2, varscan2
- FGF12 | c.445G>A p.E149K (on ENST00000454309 / NM_021032.5; = p.E87K on NM_004113.6) | Missense Mutation (SNP) | VAF 85/212 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV53167371; called by muse, mutect2, varscan2
- FGFR2 | c.629G>A p.R210Q | Missense Mutation (SNP) | VAF 45/128 reads (35%) | SIFT deleterious (0.02); PolyPhen probably damaging (1); catalogued as COSV60640963; called by muse, mutect2, varscan2
- FILIP1 | c.757G>A p.E253K | Missense Mutation (SNP) | VAF 91/222 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV99384248; called by muse, mutect2, varscan2
- FLACC1 | c.371C>T p.T124I | Missense Mutation (SNP) | VAF 43/132 reads (33%) | SIFT deleterious (0.03); PolyPhen benign (0.009); catalogued as rs768999268, COSV99629978; called by muse, mutect2, varscan2
- FLG | c.10024G>A p.D3342N | Missense Mutation (SNP) | VAF 253/695 reads (36%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.999); catalogued as COSV100911264; called by muse, mutect2, varscan2
- FLG | c.7264G>A p.E2422K | Missense Mutation (SNP) | VAF 157/402 reads (39%) | SIFT tolerated (0.52); PolyPhen benign (0.081); catalogued as rs374588791, CM071769; called by muse, mutect2, varscan2
- FLG | c.904G>A p.D302N | Missense Mutation (SNP) | VAF 139/352 reads (39%) | SIFT tolerated (0.24); PolyPhen probably damaging (0.978); catalogued as rs567082495, COSV64242945; called by muse, mutect2, varscan2
- FLG | c.16G>A p.E6K | Missense Mutation (SNP) | VAF 27/75 reads (36%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.872); catalogued as rs865914246, COSV64247427; called by muse, mutect2, varscan2
- FLG2 | c.3914C>T p.S1305F | Missense Mutation (SNP) | VAF 185/444 reads (42%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.737); catalogued as COSV101165708; called by muse, mutect2, varscan2
- FLNC | c.3923G>A p.G1308E | Missense Mutation (SNP) | VAF 31/123 reads (25%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.601); catalogued as rs773919850, COSV100367810; called by muse, mutect2, varscan2
- FLT1 | c.2056G>A p.G686S | Missense Mutation (SNP) | VAF 65/124 reads (52%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV56743082; called by muse, mutect2, varscan2
- FLT1 | c.1144C>T p.R382C | Missense Mutation (SNP) | VAF 49/84 reads (58%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs766489043, COSV56724787; called by muse, mutect2, varscan2
- FLT1 | c.806C>T p.P269L | Missense Mutation (SNP) | VAF 49/93 reads (53%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99151020; called by muse, mutect2, varscan2
- FMN2 | c.3530C>A p.P1177H | Missense Mutation (SNP) | VAF 19/42 reads (45%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.988); catalogued as rs1479518575, COSV100142894, COSV100144053; called by muse, mutect2, varscan2
- FMN2 | c.4106G>A p.G1369E | Missense Mutation (SNP) | VAF 60/160 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV60460885; called by muse, mutect2, varscan2
- FMO1 | c.550G>A p.D184N | Missense Mutation (SNP) | VAF 64/143 reads (45%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.601); catalogued as rs1407348271, COSV61447810; called by muse, mutect2, varscan2
- FMO3 | c.856G>A p.D286N | Missense Mutation (SNP) | VAF 33/68 reads (49%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.999); catalogued as rs777342108, COSV63008492; called by muse, mutect2, varscan2
- FMO3 | c.1402C>T p.P468S | Missense Mutation (SNP) | VAF 49/116 reads (42%) | SIFT tolerated (0.2); PolyPhen benign (0.061); catalogued as rs758899175, COSV63008970; called by muse, mutect2, varscan2
- FNDC3A | c.2942C>T p.T981I (on ENST00000492622 / NM_001079673.2; = p.T925I on NM_014923.5) | Missense Mutation (SNP) | VAF 11/165 reads (7%) | SIFT deleterious (0); PolyPhen benign (0.218); catalogued as COSV101256670; called by muse, mutect2
- FNDC3B | c.373C>T p.P125S | Missense Mutation (SNP) | VAF 85/214 reads (40%) | SIFT tolerated (0.05); PolyPhen probably damaging (0.979); catalogued as COSV100393863; called by muse, mutect2, varscan2
- FOXD4 | c.235C>T p.P79S | Missense Mutation (SNP) | VAF 60/100 reads (60%) | SIFT tolerated (1); PolyPhen benign (0.001); catalogued as COSV100070731; called by muse, mutect2, varscan2
- FOXI1 | c.803C>T p.P268L | Missense Mutation (SNP) | VAF 39/113 reads (35%) | SIFT tolerated (0.06); PolyPhen benign (0); catalogued as COSV100089176; called by muse, mutect2, varscan2
- FOXO1 | c.895C>T p.P299S | Missense Mutation (SNP) | VAF 30/57 reads (53%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV101091870; called by muse, mutect2, varscan2
- FOXO4 | c.107C>T p.P36L | Missense Mutation (SNP) | VAF 12/30 reads (40%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.686); catalogued as COSV100446818; called by muse, mutect2, varscan2
- FREM2 | c.8036C>T p.S2679F | Missense Mutation (SNP) | VAF 40/79 reads (51%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV99747708; called by muse, mutect2, varscan2
- FREM2 | c.8406T>G p.F2802L | Missense Mutation (SNP) | VAF 91/177 reads (51%) | SIFT tolerated (0.07); PolyPhen benign (0.127); catalogued as COSV99747714; called by muse, mutect2, varscan2
- FRK | c.562G>A p.E188K | Missense Mutation (SNP) | VAF 82/215 reads (38%) | SIFT tolerated (0.08); PolyPhen benign (0.018); catalogued as rs753596132, COSV73384053; called by muse, mutect2, varscan2
- FRMPD2 | c.3212C>T p.S1071L | Missense Mutation (SNP) | VAF 12/31 reads (39%) | SIFT tolerated (0.48); PolyPhen benign (0.013); catalogued as rs782809327, COSV100563664; called by muse, mutect2, varscan2
- FRMPD3 | c.1741G>A p.E581K | Missense Mutation (SNP) | VAF 58/140 reads (41%) | SIFT deleterious (0); PolyPhen benign (0.247); catalogued as rs750852072, COSV99345917; called by muse, mutect2, varscan2
- FRMPD3 | c.4549G>A p.E1517K | Missense Mutation (SNP) | VAF 71/212 reads (33%) | SIFT tolerated (0.05); PolyPhen probably damaging (0.958); catalogued as rs775247008, COSV99345918; called by muse, mutect2, varscan2
- FRYL | c.3718C>T p.R1240C | Missense Mutation (SNP) | VAF 41/68 reads (60%) | SIFT tolerated (0.19); PolyPhen possibly damaging (0.891); catalogued as rs773621928, COSV51947315; called by muse, mutect2, varscan2
- FRZB | c.22G>A p.G8R | Missense Mutation (SNP) | VAF 5/9 reads (56%) | SIFT tolerated, low confidence (0.14); PolyPhen benign (0); catalogued as rs1270367572, COSV99717315; called by muse, mutect2, varscan2
- FSD1 | c.622G>A p.E208K | Missense Mutation (SNP) | VAF 15/31 reads (48%) | SIFT tolerated (0.19); PolyPhen possibly damaging (0.679); catalogued as rs752854838, COSV99696658; called by muse, mutect2, varscan2
- G6PC2 | c.178G>A p.V60I | Missense Mutation (SNP) | VAF 25/86 reads (29%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.672); catalogued as rs1161714920, COSV99960697; called by muse, mutect2, varscan2
- G6PD | c.899C>T p.A300V | Missense Mutation (SNP) | VAF 47/150 reads (31%) | SIFT tolerated (0.46); PolyPhen benign (0); catalogued as COSV100854977; called by muse, mutect2, varscan2
- G6PD | c.725G>A p.G242D | Missense Mutation (SNP) | VAF 38/119 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100854978; called by muse, mutect2, varscan2
- GABRA3 | c.391G>A p.G131S | Missense Mutation (SNP) | VAF 41/110 reads (37%) | SIFT tolerated (0.43); PolyPhen probably damaging (0.999); catalogued as COSV100942506; called by muse, varscan2
- GABRB3 | c.241G>A p.D81N | Missense Mutation (SNP) | VAF 20/63 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV100159003, COSV54674034; called by muse, mutect2, varscan2
- GALNT14 | c.1520C>T p.S507F | Missense Mutation (SNP) | VAF 28/101 reads (28%) | SIFT deleterious (0.01); PolyPhen benign (0.106); catalogued as rs781693188, COSV100204347; called by muse, mutect2, varscan2
- GALNTL6 | c.1792C>T p.H598Y | Missense Mutation (SNP) | VAF 31/42 reads (74%) | SIFT tolerated, low confidence (0.45); PolyPhen benign (0); catalogued as COSV101560179; called by muse, mutect2, varscan2
- GBE1 | c.1726C>T p.R576C | Missense Mutation (SNP) | VAF 24/60 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as rs183019204, COSV101450122; called by muse, mutect2, varscan2
- GCLM | c.130C>T p.H44Y | Missense Mutation (SNP) | VAF 31/90 reads (34%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV100933979; called by muse, mutect2, varscan2
- GCN1 | c.2971G>A p.E991K | Missense Mutation (SNP) | VAF 40/100 reads (40%) | SIFT tolerated (0.67); PolyPhen benign (0.048); catalogued as COSV100324854; called by muse, mutect2, varscan2
- GCNA | c.1463C>G p.T488S | Missense Mutation (SNP) | VAF 16/29 reads (55%) | SIFT tolerated, low confidence (0.16); PolyPhen benign (0.031); catalogued as COSV101032457; called by muse, mutect2, varscan2
- GCNT3 | c.466C>T p.P156S | Missense Mutation (SNP) | VAF 51/156 reads (33%) | SIFT deleterious (0.02); PolyPhen probably damaging (1); catalogued as COSV101251772; called by muse, mutect2, varscan2
- GEMIN4 | c.185C>A p.P62H | Missense Mutation (SNP) | VAF 16/53 reads (30%) | SIFT tolerated (0.28); PolyPhen benign (0.007); catalogued as COSV100031740; called by muse, mutect2, varscan2
- GEN1 | c.1535C>A p.S512Y | Missense Mutation (SNP) | VAF 29/92 reads (32%) | SIFT tolerated (0.61); PolyPhen benign (0.181); catalogued as COSV58055185; called by muse, mutect2, varscan2
- GFM2 | c.596A>C p.K199T | Missense Mutation (SNP) | VAF 39/74 reads (53%) | SIFT deleterious (0); PolyPhen probably damaging (0.985); catalogued as COSV99714175; called by muse, mutect2, varscan2
- GFRAL | c.29G>A p.G10E | Missense Mutation (SNP) | VAF 17/53 reads (32%) | SIFT tolerated (0.3); PolyPhen benign (0.055); catalogued as COSV61235680; called by muse, mutect2, varscan2
- GFRAL | c.901G>A p.E301K | Missense Mutation (SNP) | VAF 51/129 reads (40%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.622); catalogued as COSV61229588; called by muse, mutect2, varscan2
- GFRAL | c.1157C>T p.S386L | Missense Mutation (SNP) | VAF 46/146 reads (32%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.476); catalogued as rs1321175932, COSV100474848; called by muse, mutect2, varscan2
- GGN | c.941G>A p.G314E | Missense Mutation (SNP) | VAF 9/29 reads (31%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.999); catalogued as rs1178476636, COSV99287371; called by muse, mutect2, varscan2
- GIMAP1 | c.418G>A p.G140R | Missense Mutation (SNP) | VAF 22/121 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1252849252, COSV100211967, COSV56189089; called by muse, mutect2, varscan2
- GIMAP1 | c.419G>A p.G140E | Missense Mutation (SNP) | VAF 22/119 reads (18%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.979); catalogued as COSV100212028; called by muse, varscan2
- GIMAP5 | c.152C>T p.P51L | Missense Mutation (SNP) | VAF 75/149 reads (50%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.501); catalogued as COSV100500222; called by muse, mutect2, varscan2
- GIMAP5 | c.523G>A p.D175N | Missense Mutation (SNP) | VAF 51/267 reads (19%) | SIFT tolerated (0.32); PolyPhen benign (0.105); catalogued as COSV100500223; called by muse, mutect2, varscan2
- GIMAP6 | c.832G>A p.E278K | Missense Mutation (SNP) | VAF 50/163 reads (31%) | SIFT tolerated (0.26); PolyPhen benign (0.042); catalogued as rs865805939, COSV61032437; called by muse, mutect2, varscan2
2,757 further variants in this file (1,536 protein-altering or splice-affecting, 1,124 silent, 97 other) are not listed here.
